Somatic mutation profile of tumor specimen TCGA-D3-A8GK-06A (aliquot TCGA-D3-A8GK-06A-11D-A372-08) from TCGA case TCGA-D3-A8GK, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 50.5 years (18,437 days).
Specimen TCGA-D3-A8GK-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d3f8fa82-e125-4873-bd79-1bdc8b8debde.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D3-A8GK-10A (Blood Derived Normal), aliquot TCGA-D3-A8GK-10A-01D-A375-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1c6aa641-08d8-4939-991e-79168942a26e

The open-access MAF lists 676 somatic variants for this specimen: 445 protein-altering or splice-affecting, 218 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 397, Silent 218, Nonsense Mutation 31, Frame Shift Del 9, Intron 5, RNA 4, Splice Site 3, 3'UTR 2, Splice Region 2, 5'UTR 1, In Frame Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DARS1 | c.1459C>T p.R487C | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587776984, CM133675, COSV51537400; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1267G>T p.G423* (on ENST00000281708 / NM_001349798.2; = p.G343* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 77/211 reads (36%) | hotspot (GDC flag); catalogued as COSV55896970, COSV55902795, COSV55936902; called by muse, mutect2, varscan2
- MYBPC3 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.254); catalogued as rs397516074, CM981322, COSV99920527; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 85/162 reads (52%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RP1 | c.607G>A p.G203R | Missense Mutation (SNP) | VAF 61/140 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs786205589, CM1312797, CM149188, COSV99607784; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA5 | c.868T>A p.L290I | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.985); catalogued as COSV101201115, COSV101201176; called by muse, mutect2, varscan2
- ABCB11 | c.1430G>A p.G477E | Missense Mutation (SNP) | VAF 98/198 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55588002; called by muse, mutect2, varscan2
- ABHD13 | c.565C>T p.L189F | Missense Mutation (SNP) | VAF 46/96 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.807); catalogued as rs763931167, COSV101024034, COSV65534918; called by muse, mutect2, varscan2
- ABHD13 | c.566T>A p.L189H | Missense Mutation (SNP) | VAF 45/94 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101024194; called by muse, mutect2, varscan2
- AC005833.1 | c.979G>A p.G327R | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV52900300; called by muse, mutect2, varscan2
- ADAM29 | c.1877C>A p.S626* | Nonsense Mutation (SNP) | VAF 45/103 reads (44%) | catalogued as COSV100822048; called by muse, mutect2, varscan2
- ADGRG2 | c.316C>A p.Q106K (on ENST00000379869 / NM_001079858.3; = p.Q103K on NM_005756.4) | Missense Mutation (SNP) | VAF 96/99 reads (97%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.23); catalogued as COSV100492363; called by muse, mutect2, varscan2
- ADGRV1 | c.12424C>T p.R4142W | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.642); catalogued as rs534226753, COSV67978187; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADGRV1 | c.15644C>T p.S5215F | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV67996191; called by muse, mutect2, varscan2
- ADH1B | c.1030G>A p.D344N | Missense Mutation (SNP) | VAF 59/134 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.772); catalogued as COSV100520792; called by muse, mutect2, varscan2
- ADNP | c.1865C>T p.T622I | Missense Mutation (SNP) | VAF 119/256 reads (46%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.944); catalogued as COSV62424576; called by muse, mutect2, varscan2
- AHNAK | c.842C>T p.S281L | Missense Mutation (SNP) | VAF 53/130 reads (41%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.983); catalogued as COSV99947949; called by muse, mutect2, varscan2
- AHNAK2 | c.13112T>C p.V4371A | Missense Mutation (SNP) | VAF 171/272 reads (63%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.821); catalogued as rs1159932106, COSV100317856; called by muse, mutect2, varscan2
- AIFM2 | c.461G>A p.G154E | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100325731; called by muse, mutect2, varscan2
- AKAP9 | c.557G>A p.G186E | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs896283872, COSV100662530; called by muse, mutect2, varscan2
- ALDH8A1 | c.683C>T p.S228F | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs267600821, COSV99664802; called by muse, mutect2, varscan2
- ALMS1 | c.11591C>T p.A3864V | Missense Mutation (SNP) | VAF 78/175 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as COSV100042762; called by muse, mutect2, varscan2
- ALS2 | c.212G>A p.R71K | Missense Mutation (SNP) | VAF 58/130 reads (45%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV99969446; called by muse, varscan2
- AMPD1 | c.1407G>A p.W469* | Nonsense Mutation (SNP) | VAF 28/80 reads (35%) | catalogued as COSV100815085, COSV62418974; called by muse, mutect2, varscan2
- ANGPT1 | c.1394G>A p.G465E | Missense Mutation (SNP) | VAF 55/152 reads (36%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.943); catalogued as COSV99863139; called by muse, mutect2, varscan2
- ANK1 | c.3109G>A p.D1037N | Missense Mutation (SNP) | VAF 84/196 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.665); catalogued as COSV99225602; called by muse, mutect2, varscan2
- ANK3 | c.7334C>A p.S2445* | Nonsense Mutation (SNP) | VAF 78/168 reads (46%) | catalogued as COSV99780448; called by muse, mutect2, varscan2
- ANK3 | c.6160G>A p.E2054K | Missense Mutation (SNP) | VAF 99/211 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.214); catalogued as COSV99780450; called by muse, mutect2, varscan2
- ANKFN1 | c.953T>C p.L318S | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.543); catalogued as COSV100593625; called by muse, mutect2, varscan2
- ANKRD13B | c.1007C>A p.T336N | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.14); catalogued as COSV100801309; called by muse, mutect2, varscan2
- ANKRD30A | c.2960G>A p.G987E (on ENST00000611781; = p.G931E on NM_052997.2) | Missense Mutation (SNP) | VAF 48/115 reads (42%) | SIFT tolerated (0.7); PolyPhen benign (0.019); catalogued as COSV64620926, COSV64623054; called by muse, mutect2, varscan2
- ANKRD30A | c.3166G>A p.E1056K (on ENST00000611781; = p.E1000K on NM_052997.2) | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.125); catalogued as rs746442980, COSV64610968; called by muse, mutect2, varscan2
- ANO4 | c.2285C>T p.S762L (on ENST00000392977 / NM_001286615.2; = p.S727L on NM_178826.4) | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.372); catalogued as rs1282357180, COSV100153064, COSV54598256; called by muse, mutect2, varscan2
- APOA4 | c.539G>A p.R180K | Missense Mutation (SNP) | VAF 74/192 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV100759339, COSV63360812; called by muse, mutect2, varscan2
- APOB | c.9928C>T p.P3310S | Missense Mutation (SNP) | VAF 51/99 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.172); catalogued as COSV99266092; called by muse, mutect2, varscan2
- ARHGAP15 | c.359C>T p.S120F | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV99711416; called by muse, mutect2, varscan2
- ARHGAP26 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749597249, COSV50828807; called by muse, mutect2, varscan2
- ARHGAP45 | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99566036; called by mutect2, varscan2
- ARMC4 | c.1519G>A p.E507K | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV100536978; called by muse, mutect2, varscan2
- ASPM | c.6889C>T p.R2297W | Missense Mutation (SNP) | VAF 78/325 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759104234, COSV99660564; called by muse, mutect2, varscan2
- ASXL3 | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 44/74 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV52478934; called by muse, mutect2, varscan2
- ATP10D | c.1153C>T p.P385S | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1215309523, COSV56705583; called by muse, mutect2, varscan2
- ATRX | c.4553G>A p.R1518K | Missense Mutation (SNP) | VAF 100/114 reads (88%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as COSV100970929; called by muse, mutect2, varscan2
- AXDND1 | c.1873C>T p.P625S | Missense Mutation (SNP) | VAF 43/186 reads (23%) | SIFT tolerated (0.87); PolyPhen benign (0.007); catalogued as COSV62640149; called by muse, mutect2, varscan2
- BDP1 | c.3704C>T p.S1235F | Missense Mutation (SNP) | VAF 48/129 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.105); catalogued as COSV62428909; called by muse, mutect2, varscan2
- BMPER | c.1838G>A p.G613D | Missense Mutation (SNP) | VAF 60/96 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV99779786; called by muse, mutect2, varscan2
- C2orf49 | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV99307526; called by muse, mutect2, varscan2
- C3orf20 | c.1637A>G p.K546R | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT tolerated (0.41); PolyPhen benign (0.026); catalogued as COSV99514139; called by muse, mutect2, varscan2
- CACNA1D | c.1496C>T p.S499F (on ENST00000350061 / NM_001128840.3; = p.S519F on NM_000720.4) | Missense Mutation (SNP) | VAF 103/250 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs144884666; called by muse, mutect2, varscan2
- CACNA1I | c.1112C>T p.S371F | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100360593; called by muse, mutect2
- CACNA2D3 | c.1807G>A p.D603N | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.414); catalogued as COSV99874349; called by muse, mutect2, varscan2
- CADPS | c.1201G>A p.E401K | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV99338868; called by muse, mutect2, varscan2
- CAPN9 | c.1162G>A p.D388N | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV99680567; called by muse, mutect2, varscan2
- CCDC110 | c.1843C>T p.Q615* | Nonsense Mutation (SNP) | VAF 48/103 reads (47%) | catalogued as rs1316145749, COSV100293995; called by muse, mutect2, varscan2
- CCDC158 | c.2894C>A p.S965Y | Missense Mutation (SNP) | VAF 75/159 reads (47%) | SIFT tolerated (0.47); PolyPhen benign (0.26); catalogued as COSV101187272; called by muse, mutect2, varscan2
- CCDC30 | c.1985G>A p.R662Q (on ENST00000340612; = p.R619Q on NM_001080850.3) | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.938); catalogued as rs774679471, COSV59604932; called by muse, mutect2, varscan2
- CCDC88C | c.1220G>A p.R407Q | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as COSV66236103; called by muse, mutect2, varscan2
- CCSAP | c.604C>G p.H202D | Missense Mutation (SNP) | VAF 59/226 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV52909933, COSV99497426; called by muse, mutect2, varscan2
- CD163L1 | c.979G>A p.D327N | Missense Mutation (SNP) | VAF 45/127 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.446); catalogued as COSV100550189; called by muse, mutect2, varscan2
- CD1A | c.215G>A p.R72K | Missense Mutation (SNP) | VAF 31/141 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV99192439; called by muse, mutect2
- CD2AP | c.1097C>T p.P366L | Missense Mutation (SNP) | VAF 63/68 reads (93%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV100830468; called by muse, mutect2, varscan2
- CD44 | c.2098A>G p.N700D | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99555809; called by muse, mutect2, varscan2
- CDH7 | c.307G>A p.D103N | Missense Mutation (SNP) | VAF 51/92 reads (55%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.901); catalogued as rs776542846, COSV59897249; called by muse, mutect2, varscan2
- CDH8 | c.1603C>T p.L535F | Missense Mutation (SNP) | VAF 50/105 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); catalogued as rs534947230, COSV100182134; called by muse, mutect2, varscan2
- CDK14 | c.1342G>A p.G448R (on ENST00000380050 / NM_001287135.2; = p.G430R on NM_012395.3) | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.997); catalogued as COSV99725751; called by muse, mutect2, varscan2
- CENPE | c.1340C>T p.T447I | Missense Mutation (SNP) | VAF 39/73 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.086); catalogued as rs1326722927, COSV99478216; called by muse, mutect2, varscan2
- CEP350 | c.8504C>T p.P2835L | Missense Mutation (SNP) | VAF 37/55 reads (67%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as COSV100854859; called by muse, mutect2, varscan2
- CFAP100 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs182563239, COSV61504071; called by muse, mutect2, varscan2
- CFAP45 | c.770G>A p.G257E | Missense Mutation (SNP) | VAF 175/252 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63648513; called by muse, mutect2, varscan2
- CFAP74 | c.549C>A p.F183L | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54570824; called by muse, varscan2
- CHDH | c.1438C>T p.P480S | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.053); catalogued as COSV99858537; called by muse, mutect2, varscan2
- CHGA | c.733C>T p.P245S | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.009); catalogued as rs1407202303, COSV99381185; called by muse, varscan2
- CHRM3 | c.587C>T p.S196F | Missense Mutation (SNP) | VAF 74/366 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55084430; called by muse, varscan2
- CLUH | c.3865G>T p.A1289S (on ENST00000435359; = p.A1328S on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs959037279, COSV101425774; called by muse, mutect2
- CMYA5 | c.6289C>T p.P2097S | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.001); catalogued as COSV71409139; called by muse, mutect2, varscan2
- CNGA1 | c.1649G>A p.G550E | Missense Mutation (SNP) | VAF 72/172 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100652198; called by muse, mutect2, varscan2
- CNGA3 | c.1837G>A p.D613N | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as rs144627146; called by muse, mutect2, varscan2
- COG1 | c.2207G>A p.R736Q | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs1407354647, COSV100245343; called by muse, mutect2, varscan2
- COL12A1 | c.2785C>T p.P929S | Missense Mutation (SNP) | VAF 56/119 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100486122; called by muse, mutect2, varscan2
- COL28A1 | c.1304G>A p.G435E | Missense Mutation (SNP) | VAF 49/100 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as rs1187420993, COSV101258693; called by muse, mutect2, varscan2
- COL28A1 | c.1303G>A p.G435R | Missense Mutation (SNP) | VAF 50/101 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.149); catalogued as rs1387828912, COSV101258695; called by muse, mutect2, varscan2
- COL6A3 | c.6163C>T p.P2055S | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV99798996; called by muse, mutect2, varscan2
- COL6A6 | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV100650368; called by muse, mutect2, varscan2
- COL8A1 | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.058); catalogued as COSV99657927; called by muse, mutect2, varscan2
- CPAMD8 | c.1702C>T p.R568C (on ENST00000651564; = p.R521C on NM_015692.5) | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT tolerated (0.09); PolyPhen benign (0.067); catalogued as rs762584662, COSV52230795; called by muse, mutect2, varscan2
- CPO | c.270C>T p.I90= | Splice Region (SNP) | VAF 79/174 reads (45%) | catalogued as COSV99786531; called by muse, mutect2, varscan2
- CPSF6 | c.805C>T p.R269* | Nonsense Mutation (SNP) | VAF 37/81 reads (46%) | catalogued as COSV57014021, COSV99879512; called by muse, mutect2, varscan2
- CPVL | c.694G>A p.G232R | Missense Mutation (SNP) | VAF 54/95 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775870649, COSV55301375; called by muse, mutect2, varscan2
- CPXM2 | c.2012G>A p.R671Q | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.774); catalogued as rs746636608, COSV53871092; called by muse, mutect2, varscan2
- CREB3L3 | c.479G>A p.R160K | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.82); PolyPhen benign (0.006); catalogued as rs368324133; called by muse, mutect2, varscan2
- CSF2RA | c.1027G>A p.G343S | Missense Mutation (SNP) | VAF 123/275 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0.049); catalogued as rs1186460962, COSV100817793; called by muse, mutect2, varscan2
- CSF2RA | c.1028G>A p.G343D | Missense Mutation (SNP) | VAF 120/268 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.554); catalogued as COSV100817795; called by muse, mutect2, varscan2
- CSF3R | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100117830; called by muse, mutect2, varscan2
- CSMD1 | c.3307G>A p.A1103T (on ENST00000520002; = p.A1102T on NM_033225.6) | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100149331, COSV99064816; called by muse, mutect2, varscan2
- CSMD2 | c.4387G>A p.E1463K | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.542); catalogued as COSV99591373; called by muse, mutect2, varscan2
- CSMD2 | c.1253C>T p.S418F | Missense Mutation (SNP) | VAF 48/123 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1355609119, COSV53911378; called by muse, mutect2, varscan2
- CSPG4 | c.2996C>T p.A999V | Missense Mutation (SNP) | VAF 44/94 reads (47%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.643); catalogued as COSV100413835; called by muse, mutect2, varscan2
- CTR9 | c.1340C>T p.A447V | Missense Mutation (SNP) | VAF 50/107 reads (47%) | SIFT tolerated (0.95); PolyPhen benign (0.028); catalogued as COSV100797385; called by muse, mutect2, varscan2
- DDX3X | c.850G>A p.E284K (on ENST00000399959; = p.E285K on NM_001356.5) | Missense Mutation (SNP) | VAF 16/17 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67864532; called by muse, mutect2, varscan2
- DDX51 | c.1960G>T p.E654* | Nonsense Mutation (SNP) | VAF 28/60 reads (47%) | catalogued as rs1383769895, COSV100223094, COSV57957637; called by muse, mutect2, varscan2
- DDX60L | c.374G>A p.G125E | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.743); catalogued as COSV99487752; called by muse, mutect2, varscan2
- DEFB118 | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 41/76 reads (54%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0); catalogued as rs1360293476, COSV53621199; called by muse, mutect2, varscan2
- DGKG | c.703G>A p.D235N | Missense Mutation (SNP) | VAF 65/158 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.171); catalogued as rs201046590, COSV99403559; called by muse, mutect2, varscan2
- DLGAP5 | c.1261G>A p.G421S | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.086); catalogued as COSV99903940; called by muse, mutect2, varscan2
- DMD | c.4133C>T p.S1378F | Missense Mutation (SNP) | VAF 46/51 reads (90%) | SIFT deleterious (0.02); PolyPhen benign (0.242); catalogued as COSV100820252; called by muse, varscan2
- DNAH2 | c.4630G>C p.E1544Q | Missense Mutation (SNP) | VAF 53/113 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV101209413; called by muse, mutect2, varscan2
- DNAH5 | c.7805G>A p.G2602E | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.589); catalogued as rs199901657, COSV54260476; called by muse, varscan2
- DNAH9 | c.9280G>A p.E3094K | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV52376416; called by muse, mutect2, varscan2
- DOCK11 | c.965C>T p.T322I | Missense Mutation (SNP) | VAF 34/37 reads (92%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as COSV99354065; called by muse, mutect2, varscan2
- DOK6 | c.599+1G>A p.X200_splice | Splice Site (SNP) | VAF 11/29 reads (38%) | catalogued as rs750509057, COSV101234558; called by muse, mutect2, varscan2
- DPP8 | c.1195C>T p.Q399* (on ENST00000341861 / NM_001320875.2; = p.Q383* on NM_017743.6) | Nonsense Mutation (SNP) | VAF 33/38 reads (87%) | catalogued as COSV100202420; called by muse, mutect2, varscan2
- DSCAML1 | c.5789C>T p.T1930I (on ENST00000321322; = p.T1870I on NM_020693.4) | Missense Mutation (SNP) | VAF 87/200 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV100356249; called by muse, mutect2, varscan2
- DUOX2 | c.1843C>T p.L615F | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs764860888, COSV101199796; called by muse, mutect2, varscan2
- DUSP21 | c.166G>A p.V56M | Missense Mutation (SNP) | VAF 56/65 reads (86%) | SIFT tolerated (0.1); PolyPhen benign (0.205); catalogued as COSV100173599; called by muse, mutect2, varscan2
- DVL3 | c.52C>T p.L18F | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100493696; called by muse, mutect2, varscan2
- DYNAP | c.82G>A p.D28N (on ENST00000321600; = p.D2N on NM_173629.3) | Missense Mutation (SNP) | VAF 66/127 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.61); catalogued as rs911766804, COSV100391764; called by muse, mutect2, varscan2
- ECPAS | c.3247G>C p.A1083P | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99398508; called by muse, mutect2, varscan2
- EEF2 | c.1196C>T p.S399F | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV100500815; called by muse, mutect2, varscan2
- EME1 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV99868984; called by muse, mutect2, varscan2
- EMILIN3 | c.1879G>A p.E627K | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.76); catalogued as COSV100182730, COSV60035996; called by muse, mutect2, varscan2
- ENPP2 | c.1780G>A p.E594K (on ENST00000075322 / NM_001040092.3; = p.E646K on NM_006209.5) | Missense Mutation (SNP) | VAF 198/438 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99308500; called by muse, mutect2, varscan2
- ENTPD3 | c.838C>A p.P280T | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV100088767; called by muse, mutect2, varscan2
- EP400 | c.5130G>T p.L1710F | Missense Mutation (SNP) | VAF 41/74 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV100201386, COSV57787329; called by muse, mutect2, varscan2
- EP400 | c.6098C>T p.P2033L | Missense Mutation (SNP) | VAF 93/206 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100201391; called by muse, mutect2, varscan2
- EPPK1 | c.3760C>T p.Q1254* | Nonsense Mutation (SNP) | VAF 7/15 reads (47%) | catalogued as rs1554660363, COSV101599874; called by muse, mutect2, varscan2
- ERICH3 | c.3964G>A p.G1322R | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.361); catalogued as rs769725102, COSV100444678; called by muse, mutect2, varscan2
- EXOC1 | c.1838T>C p.L613S | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100637903; called by muse, mutect2, varscan2
- F8 | c.4949G>A p.R1650K | Missense Mutation (SNP) | VAF 71/77 reads (92%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100811611; called by muse, mutect2, varscan2
- FAM135B | c.3193C>T p.P1065S | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52709656, COSV52715574, COSV52746385; called by muse, mutect2, varscan2
- FAM13C | c.1393G>A p.D465N | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV99514012; called by muse, mutect2, varscan2
- FAM13C | c.818C>T p.S273L | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99514015; called by muse, mutect2, varscan2
- FAM227B | c.802C>T p.P268S | Missense Mutation (SNP) | VAF 95/251 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54816732; called by muse, mutect2, varscan2
- FAP | c.191G>C p.G64A | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as COSV99502240; called by muse, mutect2, varscan2
- FBXO41 | c.1186G>A p.G396S | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.75); PolyPhen benign (0.16); catalogued as rs1178941292, COSV99721296; called by muse, mutect2, varscan2
- FBXO5 | c.1037C>T p.S346F | Missense Mutation (SNP) | VAF 49/106 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.525); catalogued as rs1367399381, COSV99999853; called by muse, mutect2, varscan2
- FBXW7 | c.1597T>C p.C533R (on ENST00000281708 / NM_001349798.2; = p.C453R on NM_018315.5) | Missense Mutation (SNP) | VAF 57/119 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55966252; called by muse, mutect2, varscan2
- FCRL5 | c.92G>A p.W31* | Nonsense Mutation (SNP) | VAF 154/237 reads (65%) | catalogued as rs1445181102, COSV100709012; called by muse, mutect2, varscan2
- FNDC7 | c.1195G>A p.E399K | Missense Mutation (SNP) | VAF 80/142 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as rs202035625, COSV99601002; called by muse, mutect2, varscan2
- FPR1 | c.433G>A p.V145M | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.808); catalogued as COSV100494126; called by muse, mutect2, varscan2
- FRAS1 | c.7546C>T p.R2516C | Missense Mutation (SNP) | VAF 131/277 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs374802955; called by muse, mutect2, varscan2
- FRAS1 | c.9010G>A p.E3004K | Missense Mutation (SNP) | VAF 72/155 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1470070058, COSV53627571; called by muse, mutect2, varscan2
- FSIP1 | c.613C>T p.P205S | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.324); catalogued as rs769904999, COSV63227171; called by muse, mutect2, varscan2
- FUCA1 | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 72/159 reads (45%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV100992166; called by muse, mutect2
- FUT10 | c.13C>T p.Q5* | Nonsense Mutation (SNP) | VAF 15/42 reads (36%) | catalogued as COSV100161515; called by muse, mutect2, varscan2
- GABPB1 | c.1051C>T p.Q351* | Nonsense Mutation (SNP) | VAF 33/88 reads (38%) | catalogued as rs1208177883, COSV99589847; called by muse, mutect2, varscan2
- GABRA3 | c.110C>T p.P37L | Missense Mutation (SNP) | VAF 93/100 reads (93%) | SIFT tolerated, low confidence (0.39); PolyPhen probably damaging (0.981); catalogued as COSV100942895; called by muse, mutect2, varscan2
- GATM | c.815T>C p.V272A | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV101188306; called by muse, mutect2, varscan2
- GBF1 | c.1687-1G>A p.X563_splice (on ENST00000369983 / NM_001377137.1; = p.X562_splice on NM_004193.3) | Splice Site (SNP) | VAF 42/109 reads (39%) | catalogued as COSV100890526; called by muse, mutect2, varscan2
- GCC1 | c.454G>C p.G152R | Missense Mutation (SNP) | VAF 44/93 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.036); catalogued as COSV99133806; called by muse, mutect2
- GCC1 | c.452G>T p.G151V | Missense Mutation (SNP) | VAF 47/95 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.122); catalogued as COSV50002247; called by muse, mutect2
- GDF5 | c.428C>T p.S143F | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.27); catalogued as COSV65503220; called by muse, mutect2, varscan2
- GID4 | c.460T>A p.Y154N | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.406); catalogued as COSV99254213; called by muse, mutect2, varscan2
- GIMAP8 | c.1945G>A p.E649K | Missense Mutation (SNP) | VAF 54/105 reads (51%) | SIFT tolerated (0.28); PolyPhen benign (0.025); catalogued as COSV56229625; called by muse, mutect2, varscan2
- GLDN | c.1112G>A p.G371D | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100117768; called by muse, mutect2, varscan2
- GMPPA | c.917C>T p.S306F | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1284269427, COSV100354676; called by muse, mutect2, varscan2
- GON4L | c.1037C>T p.S346L | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs768485088, COSV99674639; called by muse, mutect2, varscan2
- GPR176 | c.1492G>A p.E498K | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.612); catalogued as COSV100137251; called by muse, mutect2, varscan2
- GRIK2 | c.1291C>T p.R431C | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as rs1269034550, COSV59752057; called by muse, mutect2, varscan2
- GRIN2A | c.1847C>T p.S616F | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100410159; called by muse, mutect2, varscan2
- H1-7 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs1415159592, COSV100622224; called by muse, mutect2, varscan2
- HBD | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 45/95 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV53082140, COSV99496475; called by muse, mutect2, varscan2
- HIP1R | c.3155A>G p.H1052R | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.006); catalogued as rs1430835962, COSV99458929; called by muse, mutect2, varscan2
- HMCN1 | c.3401C>T p.S1134L | Missense Mutation (SNP) | VAF 151/212 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99630523; called by muse, varscan2
- HMGCLL1 | c.623C>T p.P208L | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.188); catalogued as COSV99232388; called by muse, mutect2, varscan2
- HNRNPH1 | c.445G>T p.G149W | Missense Mutation (SNP) | VAF 74/171 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.562); catalogued as rs1217885373, COSV100270714; called by muse, mutect2, varscan2
- HNRNPK | c.1207A>G p.I403V | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100699036; called by muse, mutect2, varscan2
- HRNR | c.5672C>T p.S1891L | Missense Mutation (SNP) | VAF 111/2002 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.024); catalogued as COSV100913579, COSV100913581; called by muse, mutect2
- HSDL2 | c.395C>G p.A132G | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as COSV99356862, COSV99356928; called by muse, mutect2, varscan2
- HYDIN | c.14630C>T p.S4877F | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as rs752031535, COSV101125107; called by muse, mutect2
- IDO2 | c.499T>A p.F167I (on ENST00000389060; = p.F180I on NM_194294.2) | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100584797; called by muse, mutect2, varscan2
- IFNA6 | c.416C>T p.S139F | Missense Mutation (SNP) | VAF 160/391 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as rs753282137, COSV101207024; called by muse, mutect2, varscan2
- IFRD1 | c.1255C>T p.R419C | Missense Mutation (SNP) | VAF 73/134 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs866141731, COSV99134038; called by muse, mutect2, varscan2
- IGHV4-59 | c.268G>A p.V90I | Missense Mutation (SNP) | VAF 168/366 reads (46%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs782640550; called by muse, varscan2
- IL12RB1 | c.1183G>A p.G395R | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.731); catalogued as rs1288507145, COSV100443068; called by muse, mutect2, varscan2
- IL17RC | c.382C>T p.P128S (on ENST00000295981 / NM_153461.4; = p.P57S on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.597); catalogued as COSV99925072; called by muse, mutect2, varscan2
- INTS3 | c.1730C>T p.S577F | Missense Mutation (SNP) | VAF 183/261 reads (70%) | SIFT tolerated (0.11); PolyPhen benign (0.371); catalogued as COSV100016160; called by muse, mutect2, varscan2
- ITIH6 | c.2846G>A p.G949D | Missense Mutation (SNP) | VAF 29/31 reads (94%) | SIFT tolerated (0.16); PolyPhen benign (0.08); catalogued as COSV99513438; called by muse, mutect2, varscan2
- ITPR2 | c.3550G>A p.E1184K | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.675); catalogued as rs1298184018, COSV101190029, COSV101190077; called by muse, mutect2, varscan2
- IVNS1ABP | c.1187C>T p.S396F | Missense Mutation (SNP) | VAF 196/280 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); catalogued as COSV62250682; called by muse, mutect2, varscan2
- KCNB2 | c.499T>C p.F167L | Missense Mutation (SNP) | VAF 51/130 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.074); catalogued as COSV101578829; called by muse, mutect2, varscan2
- KCNH6 | c.2921C>T p.P974L | Missense Mutation (SNP) | VAF 45/90 reads (50%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV100121116; called by muse, mutect2, varscan2
- KCNH7 | c.1886G>A p.G629E | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59814394; called by muse, mutect2, varscan2
- KCNN3 | c.1006G>A p.A336T | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as rs764366056, COSV55222742; called by muse, mutect2, varscan2
- KIF12 | c.1856C>T p.A619V (on ENST00000640217; = p.A481V on NM_138424.1) | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.788); catalogued as COSV100936173; called by muse, mutect2, varscan2
- KIF13A | c.4381C>T p.P1461S | Missense Mutation (SNP) | VAF 261/273 reads (96%) | SIFT deleterious (0.01); PolyPhen benign (0.196); catalogued as COSV99436379; called by muse, mutect2, varscan2
- KIF21A | c.2494G>A p.A832T (on ENST00000361418 / NM_001378440.1; = p.A819T on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/130 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV100735499; called by muse, mutect2, varscan2
- KLRK1 | c.239A>G p.N80S | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.124); catalogued as COSV99555164; called by muse, mutect2, varscan2
- KMT2D | c.7169del p.P2390Rfs*36 | Frame Shift Del (DEL) | VAF 9/30 reads (30%) | catalogued as COSV56432484; called by mutect2, pindel, varscan2
- KRT6A | c.1535G>A p.G512E | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.684); catalogued as COSV100417034; called by muse, mutect2, varscan2
- KRT79 | c.41G>A p.G14E | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as COSV100398456; called by muse, mutect2, varscan2
- KRTAP4-4 | c.110G>A p.R37H | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.045); catalogued as rs201735937, COSV66811162; called by muse, varscan2
- LAD1 | c.1342G>A p.E448K | Missense Mutation (SNP) | VAF 211/281 reads (75%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.592); catalogued as COSV66211988; called by muse, mutect2, varscan2
- LAMA1 | c.8528C>T p.S2843F | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as rs751610284, COSV101056660; called by muse, mutect2, varscan2
- LAMA3 | c.2936C>T p.S979F | Missense Mutation (SNP) | VAF 70/199 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.077); catalogued as COSV100557020; called by muse, mutect2, varscan2
- LATS2 | c.2027T>A p.I676N | Missense Mutation (SNP) | VAF 52/109 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV101231594; called by muse, mutect2, varscan2
- LILRA1 | c.566C>T p.P189L | Missense Mutation (SNP) | VAF 67/148 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.448); catalogued as rs202039753, COSV99251952; called by mutect2, varscan2
- LIMCH1 | c.2764G>A p.D922N | Missense Mutation (SNP) | VAF 39/82 reads (48%) | SIFT tolerated (0.43); PolyPhen benign (0.05); catalogued as COSV100573921, COSV58299640; called by muse, mutect2, varscan2
- LIMCH1 | c.3056C>T p.P1019L | Missense Mutation (SNP) | VAF 64/167 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as COSV58279647; called by muse, mutect2
- LIN7A | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1423458305, COSV99692267; called by muse, mutect2, varscan2
- LPIN1 | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.824); catalogued as COSV99877702; called by muse, mutect2, varscan2
- LRP1B | c.1936C>T p.H646Y | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1158137459, COSV67234672; called by muse, mutect2, varscan2
- LRP2 | c.1715A>C p.Y572S | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99788922; called by muse, mutect2, varscan2
- LRRC1 | c.454A>T p.N152Y | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV100906417; called by muse, mutect2, varscan2
- LRRC37A | c.4962C>A p.Y1654* | Nonsense Mutation (SNP) | VAF 36/137 reads (26%) | catalogued as rs1225892060, COSV100208201; called by muse, mutect2, varscan2
- LRRK2 | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.121); catalogued as rs1422282200, COSV100110500, COSV100110942; called by muse, mutect2, varscan2
- LRRK2 | c.7574C>T p.S2525F | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.58); catalogued as COSV100110502; called by muse, mutect2, varscan2
- LSM10 | c.356C>T p.P119L | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV100240043, COSV59872417; called by muse, mutect2, varscan2
- MAB21L4 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.61); PolyPhen benign (0.037); catalogued as COSV100278556; called by muse, mutect2, varscan2
- MACF1 | c.9796C>T p.Q3266* | Nonsense Mutation (SNP) | VAF 33/88 reads (38%) | catalogued as rs1370203854, COSV99245049; called by muse, mutect2, varscan2
- MACO1 | c.686T>A p.I229N | Missense Mutation (SNP) | VAF 119/270 reads (44%) | SIFT tolerated (0.49); PolyPhen benign (0.062); catalogued as COSV100975194; called by muse, mutect2, varscan2
- MAGEC2 | c.992C>A p.S331Y | Missense Mutation (SNP) | VAF 56/63 reads (89%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99909690; called by muse, mutect2, varscan2
- MAGEC3 | c.469C>T p.P157S | Missense Mutation (SNP) | VAF 9/9 reads (100%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs559021818, COSV53580931; called by muse, varscan2
- MAN1A1 | c.538A>T p.I180F | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.042); catalogued as COSV100870379; called by muse, mutect2, varscan2
- MAP4K1 | c.2213C>T p.P738L | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); catalogued as COSV101204171, COSV101204267; called by muse, mutect2, varscan2
- MARCHF4 | c.338C>T p.S113F | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.154); catalogued as rs1402194198, COSV56104335; called by muse, mutect2, varscan2
- MBD5 | c.1135A>T p.T379S | Missense Mutation (SNP) | VAF 57/151 reads (38%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV101290125; called by muse, mutect2, varscan2
- MECOM | c.922C>T p.P308S (on ENST00000468789 / NM_001105078.4; = p.P496S on NM_004991.4) | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.158); catalogued as COSV52959050; called by muse, mutect2, varscan2
- MEGF10 | c.2987T>C p.F996S | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.43); PolyPhen benign (0.01); catalogued as rs1468434021, COSV99175025; called by muse, mutect2, varscan2
- MICAL2 | c.1675C>T p.R559W | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs138170636; called by muse, mutect2, varscan2
- MICAL3 | c.3632A>T p.D1211V | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.01); catalogued as rs1477373659, COSV101490902; called by muse, mutect2, varscan2
- MME | c.831G>A p.M277I | Missense Mutation (SNP) | VAF 63/136 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0.087); catalogued as COSV64710715; called by muse, mutect2, varscan2
- MORC1 | c.2227G>A p.E743K | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs59131790, COSV99226488; called by muse, varscan2
- MPP2 | c.1685A>T p.K562M (on ENST00000461854 / NM_001278372.2; = p.K538M on NM_005374.5) | Missense Mutation (SNP) | VAF 46/94 reads (49%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.726); catalogued as COSV99290484; called by muse, mutect2, varscan2
- MPZL3 | c.488C>T p.S163F | Missense Mutation (SNP) | VAF 43/83 reads (52%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); catalogued as rs1210715196, COSV99636341; called by muse, varscan2
- MRPL21 | c.14C>T p.S5F | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.011); catalogued as rs1016987919, COSV54821862; called by muse, mutect2, varscan2
- MTHFSD | c.206C>T p.P69L (on ENST00000360900 / NM_001159377.2; = p.P68L on NM_022764.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 107/234 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100530418; called by muse, mutect2, varscan2
- MTRR | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0); catalogued as rs760233681, COSV52941829, COSV52948066; called by muse, mutect2, varscan2
- MUC16 | c.5132G>T p.G1711V | Missense Mutation (SNP) | VAF 49/140 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.336); catalogued as COSV101200185; called by muse, mutect2, varscan2
- MUC16 | c.4214C>T p.S1405L | Missense Mutation (SNP) | VAF 45/100 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.048); catalogued as COSV67453469; called by muse, mutect2, varscan2
- MUC3A | c.8921G>A p.G2974E | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.996); catalogued as rs759534118, COSV60210190, COSV60226222; called by muse, mutect2
- MYCT1 | c.247G>A p.G83R | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100924076; called by muse, mutect2
- MYO1G | c.1205T>C p.F402S | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99348804; called by muse, mutect2, varscan2
- MYO9A | c.2836C>T p.R946* | Nonsense Mutation (SNP) | VAF 12/41 reads (29%) | catalogued as rs755573420, COSV100613720; called by muse, mutect2, varscan2
- NAA35 | c.541G>A p.G181R | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100863361, COSV64486569; called by muse, mutect2, varscan2
- NAA35 | c.542G>A p.G181E | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV100863340, COSV100863362; called by muse, mutect2, varscan2
- NCAPD3 | c.692C>T p.S231F | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV73258565; called by muse, mutect2, varscan2
- NCF1 | c.631G>C p.E211Q | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56877186, COSV99194294; called by muse, mutect2, varscan2
- NDUFS1 | c.1645G>A p.G549R | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99261067; called by muse, mutect2, varscan2
- NEB | c.10723C>T p.P3575S | Missense Mutation (SNP) | VAF 123/280 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99424263; called by muse, mutect2, varscan2
- NEIL3 | c.215T>C p.V72A | Missense Mutation (SNP) | VAF 76/160 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.053); catalogued as COSV99220604; called by muse, mutect2, varscan2
- NEO1 | c.142C>T p.R48* | Nonsense Mutation (SNP) | VAF 40/104 reads (38%) | catalogued as COSV99981192; called by muse, mutect2, varscan2
- NIM1K | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.954); catalogued as rs760522640, COSV58143142, COSV58147025; called by muse, mutect2, varscan2
- NIN | c.5062C>T p.Q1688* (on ENST00000382041 / NM_182946.1; = p.Q975* on NM_016350.4) | Nonsense Mutation (SNP) | VAF 40/106 reads (38%) | catalogued as COSV99813855; called by muse, mutect2, varscan2
- NLRP10 | c.1656G>A p.M552I | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV100150016, COSV60778962; called by muse, mutect2, varscan2
- NPIPB15 | c.1031C>T p.P344L | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); catalogued as rs1360859344, COSV70437102; called by muse, mutect2, varscan2
- NPY5R | c.201G>A p.M67I | Missense Mutation (SNP) | VAF 117/271 reads (43%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs867560945, COSV58451014; called by muse, mutect2, varscan2
- NSUN2 | c.613C>A p.P205T | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.043); catalogued as COSV99243256; called by muse, mutect2, varscan2
- NUDT10 | c.493T>C p.*165Qext*1 | Nonstop Mutation (SNP) | VAF 28/31 reads (90%) | catalogued as COSV100726829; called by muse, mutect2, varscan2
- NUP210L | c.2365C>T p.P789S | Missense Mutation (SNP) | VAF 89/133 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs1334093564, COSV99668293; called by muse, mutect2, varscan2
- NUP62 | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); catalogued as rs781692939, COSV100352135; called by muse, mutect2, varscan2
- OBSCN | c.12970C>T p.H4324Y | Missense Mutation (SNP) | VAF 75/99 reads (76%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV52828004; called by muse, mutect2, varscan2
- OR10A4 | c.860A>G p.N287S | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101139527; called by muse, mutect2
- OR2L3 | c.444G>A p.W148* | Nonsense Mutation (SNP) | VAF 99/299 reads (33%) | catalogued as rs780035611, COSV63455742, COSV63456116; called by muse, mutect2, varscan2
- OR4C16 | c.867T>A p.N289K | Missense Mutation (SNP) | VAF 43/79 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); catalogued as COSV100114100, COSV58943252; called by muse, mutect2, varscan2
- OR4K2 | c.597G>A p.M199I | Missense Mutation (SNP) | VAF 232/640 reads (36%) | SIFT tolerated (0.6); PolyPhen benign (0.085); catalogued as rs866350693, COSV53848275; called by muse, mutect2, varscan2
- OR52E2 | c.938G>A p.G313E | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs757530327, COSV100384831; called by muse, mutect2, varscan2
- OR5H15 | c.482G>A p.G161E | Missense Mutation (SNP) | VAF 66/166 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as COSV62947502, COSV62948190; called by muse, mutect2, varscan2
- OR8B4 | c.790C>T p.P264S | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.006); catalogued as rs755381467, COSV100635732, COSV100635830; called by muse, mutect2, varscan2
- OR9I1 | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100110078, COSV56926130; called by muse, mutect2, varscan2
- OSBPL3 | c.2385G>A p.M795I | Missense Mutation (SNP) | VAF 63/185 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV100514230; called by muse, mutect2, varscan2
- OTOF | c.3122C>T p.S1041F (on ENST00000272371 / NM_194248.3; = p.S294F on NM_004802.4) | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.335); catalogued as rs267599307, COSV99717946; called by muse, mutect2, varscan2
- PANX3 | c.1099G>A p.D367N | Missense Mutation (SNP) | VAF 62/131 reads (47%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as COSV99421564; called by muse, mutect2, varscan2
- PAPPA | c.641G>A p.G214D | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1474691508, COSV100074403; called by muse, mutect2, varscan2
- PARD3 | c.4001C>T p.P1334L | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1429728150, COSV100632328; called by muse, mutect2, varscan2
- PARD3 | c.4000C>T p.P1334S | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs372887395; called by muse, mutect2, varscan2
- PARD6G | c.88C>T p.R30* | Nonsense Mutation (SNP) | VAF 23/37 reads (62%) | catalogued as rs985309992, COSV100783416, COSV100783449; called by muse, mutect2, varscan2
- PCDH15 | c.4912G>A p.E1638K | Missense Mutation (SNP) | VAF 68/147 reads (46%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as rs867754850, COSV57309177; called by muse, mutect2, varscan2
- PCDHA3 | c.80G>A p.G27E | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.291); catalogued as COSV100973787; called by muse, mutect2, varscan2
- PCDHAC1 | c.853C>T p.H285Y | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.8); PolyPhen benign (0.021); catalogued as COSV99165539; called by muse, mutect2, varscan2
- PCED1B | c.363G>A p.M121I | Missense Mutation (SNP) | VAF 48/101 reads (48%) | SIFT tolerated (0.42); PolyPhen benign (0.066); catalogued as rs868095731, COSV71395414; called by muse, mutect2, varscan2
- PCLO | c.12131G>A p.R4044Q | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1271626427, COSV61619046; called by muse, mutect2, varscan2
- PCLO | c.4165C>T p.L1389F | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.668); catalogued as COSV100433670; called by muse, mutect2, varscan2
- PCYT2 | c.374C>T p.T125I | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV100155584; called by muse, mutect2, varscan2
- PDE4A | c.1783C>T p.P595S (on ENST00000380702 / NM_001111307.2; = p.P356S on NM_006202.3) | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.901); catalogued as rs1298142620, COSV99534406; called by muse, mutect2, varscan2
- PDE8A | c.2021T>C p.F674S | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100051991; called by muse, mutect2, varscan2
- PHOSPHO2 | c.361G>T p.V121L | Missense Mutation (SNP) | VAF 50/101 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs149327414, COSV99775886; called by muse, mutect2, varscan2
- PIK3C2G | c.1544C>T p.S515F | Missense Mutation (SNP) | VAF 37/67 reads (55%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.569); catalogued as COSV99852121; called by muse, mutect2, varscan2
- PIWIL2 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 77/153 reads (50%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.092); catalogued as rs1437231997, COSV63251914; called by muse, mutect2, varscan2
- PKHD1L1 | c.6820C>T p.P2274S | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1468626979, COSV101006306; called by muse, mutect2, varscan2
- PLCB4 | c.1288G>A p.D430N | Missense Mutation (SNP) | VAF 34/43 reads (79%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); catalogued as rs377059001; called by muse, mutect2, varscan2
- PLG | c.833G>A p.G278E | Missense Mutation (SNP) | VAF 87/248 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as COSV99804779; called by muse, mutect2, varscan2
- PLP2 | c.233T>C p.I78T | Missense Mutation (SNP) | VAF 35/37 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1557099414, COSV100890163; called by muse, mutect2, varscan2
- PML | c.2336C>T p.A779V | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.036); catalogued as rs1231412287, COSV99167368; called by muse, mutect2, varscan2
- POTEE | c.1228G>A p.D410N | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.134); catalogued as rs777247527, COSV100388170; called by muse, mutect2, varscan2
- POTEF | c.2269G>A p.E757K | Missense Mutation (SNP) | VAF 64/145 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.099); catalogued as COSV100665000; called by muse, mutect2, varscan2
- PPEF2 | c.1088C>T p.S363F | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs1303282455, COSV99714623; called by muse, mutect2, varscan2
- PPP3R2 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 52/109 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as rs1472868875, COSV100701373; called by muse, mutect2, varscan2
- PRB3 | c.601C>T p.P201S | Missense Mutation (SNP) | VAF 82/358 reads (23%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.877); catalogued as rs367917023, COSV99039433; called by muse, varscan2
- PRKAR2B | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as COSV99708345; called by muse, mutect2, varscan2
- PRSS36 | c.2006G>A p.R669Q | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0.024); catalogued as rs768201640, COSV51637922; called by muse, mutect2, varscan2
- PSD3 | c.932G>A p.G311E | Missense Mutation (SNP) | VAF 51/142 reads (36%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); catalogued as COSV100496462; called by muse, mutect2, varscan2
- PSD3 | c.931G>A p.G311R | Missense Mutation (SNP) | VAF 48/142 reads (34%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as rs1324826385, COSV100496108, COSV100496464; called by muse, mutect2, varscan2
- PSG8 | c.308C>T p.S103F | Missense Mutation (SNP) | VAF 178/438 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.932); catalogued as COSV100126324, COSV60612347; called by muse, mutect2, varscan2
- PSMD2 | c.2648C>T p.A883V | Missense Mutation (SNP) | VAF 58/129 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV59528964; called by muse, mutect2, varscan2
- PTDSS1 | c.1412G>A p.G471E | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT tolerated, low confidence (0.45); PolyPhen probably damaging (0.994); catalogued as COSV100428711; called by muse, mutect2, varscan2
- PTPN4 | c.2345C>T p.T782I | Missense Mutation (SNP) | VAF 56/128 reads (44%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.681); catalogued as rs756718985, COSV99750438; called by muse, mutect2, varscan2
- PTPRD | c.1996C>T p.P666S | Missense Mutation (SNP) | VAF 81/178 reads (46%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as COSV61928174; called by muse, mutect2, varscan2
- PTPRO | c.2594C>T p.S865F | Missense Mutation (SNP) | VAF 50/98 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1303410498, COSV55511735; called by muse, mutect2, varscan2
- PXDN | c.2962C>T p.H988Y | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374095501, COSV99413842; called by muse, varscan2
- RASGRP3 | c.20G>A p.G7E | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.047); catalogued as COSV101274783; called by muse, mutect2, varscan2
- RBFOX1 | c.161G>C p.G54A | Missense Mutation (SNP) | VAF 52/125 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.958); catalogued as COSV100301865; called by muse, mutect2, varscan2
- RBM46 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV99908168; called by muse, varscan2
- RBM47 | c.1175G>A p.G392E | Missense Mutation (SNP) | VAF 72/192 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99920948; called by muse, mutect2
- RCCD1 | c.656dup p.W220Lfs*8 | Frame Shift Ins (INS) | VAF 36/86 reads (42%) | catalogued as rs753185624; called by mutect2, pindel, varscan2
- RELN | c.5234G>A p.W1745* | Nonsense Mutation (SNP) | VAF 18/31 reads (58%) | catalogued as COSV100633992; called by muse, mutect2, varscan2
- RELN | c.646C>T p.P216S | Missense Mutation (SNP) | VAF 51/122 reads (42%) | SIFT tolerated (0.84); PolyPhen probably damaging (0.968); catalogued as COSV100633995; called by muse, mutect2, varscan2
- RELN | c.474-1G>A p.X158_splice | Splice Site (SNP) | VAF 30/69 reads (43%) | catalogued as COSV100633997; called by muse, mutect2, varscan2
- RGL3 | c.653C>T p.A218V | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.17); catalogued as rs373067301, COSV100805303; called by muse, mutect2, varscan2
- RGL3 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1240109539, COSV100710557; called by muse, mutect2, varscan2
- RIMS2 | c.955G>A p.E319K (on ENST00000666250 / NM_001348490.2; = p.E127K on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.675); catalogued as rs1210873564, COSV99170551; called by muse, mutect2, varscan2
- RIMS2 | c.3302G>A p.R1101Q (on ENST00000666250 / NM_001348490.2; = p.R909Q on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752574736, COSV51674365; called by muse, mutect2, varscan2
- RP1 | c.6463G>A p.D2155N | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV55110159; called by muse, mutect2, varscan2
- RPAP1 | c.2143C>T p.Q715* | Nonsense Mutation (SNP) | VAF 26/55 reads (47%) | catalogued as COSV100427178; called by muse, mutect2, varscan2
- RUBCNL | c.1849C>T p.Q617* | Nonsense Mutation (SNP) | VAF 17/35 reads (49%) | catalogued as COSV100529148; called by muse, mutect2, varscan2
- RYR1 | c.10792G>A p.E3598K | Missense Mutation (SNP) | VAF 31/52 reads (60%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.551); catalogued as rs1322440459, COSV100616015; called by muse, mutect2, varscan2
- RYR1 | c.12363G>A p.M4121I | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.43); catalogued as COSV100616017; called by muse, mutect2, varscan2
- SCAF4 | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as rs1313037147, COSV99741610; called by muse, mutect2, varscan2
- SCN11A | c.529A>G p.K177E | Missense Mutation (SNP) | VAF 63/146 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100181787; called by muse, mutect2, varscan2
- SCP2D1 | c.5G>A p.W2* | Nonsense Mutation (SNP) | VAF 20/23 reads (87%) | catalogued as COSV99602085; called by muse, mutect2, varscan2
- SDK1 | c.5282C>T p.P1761L | Missense Mutation (SNP) | VAF 39/55 reads (71%) | SIFT tolerated (0.18); PolyPhen benign (0.05); catalogued as COSV101269492; called by muse, mutect2, varscan2
- SEC16A | c.2582A>T p.E861V | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV99258857; called by muse, mutect2, varscan2
- SEC24C | c.581A>G p.Q194R | Missense Mutation (SNP) | VAF 9/139 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.274); catalogued as COSV100226919; called by muse, mutect2
- SELE | c.511G>A p.G171R | Missense Mutation (SNP) | VAF 40/58 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100324846; called by muse, mutect2, varscan2
- SEMA3G | c.1820C>T p.S607F | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV99202409; called by muse, mutect2, varscan2
- SETD5 | c.3215G>A p.R1072Q | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV56707430; called by muse, mutect2, varscan2
- SEZ6L | c.1423G>A p.G475R | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.843); catalogued as rs1355492093, COSV99962278; called by muse, mutect2
- SGMS1 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 44/91 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV62369069, COSV62370553; called by muse, mutect2, varscan2
- SH2D1B | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV100854765; called by muse, mutect2, varscan2
- SH3BP4 | c.2399C>T p.S800F | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.897); catalogued as rs186229981; called by muse, mutect2, varscan2
- SI | c.285G>A p.W95* | Nonsense Mutation (SNP) | VAF 38/70 reads (54%) | catalogued as rs923379830, COSV100015910; called by muse, mutect2, varscan2
- SIK3 | c.3226C>T p.L1076F (on ENST00000445177 / NM_001366686.2; = p.L1034F on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.462); catalogued as COSV99408183; called by muse, mutect2, varscan2
- SLC16A7 | c.71G>A p.G24E | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.288); catalogued as COSV99676590; called by muse, mutect2, varscan2
- SLC6A7 | c.581G>A p.W194* | Nonsense Mutation (SNP) | VAF 19/29 reads (66%) | catalogued as rs1400625314, COSV100046346; called by muse, mutect2, varscan2
- SLC6A9 | c.1603T>A p.S535T (on ENST00000360584 / NM_201649.4; = p.S481T on NM_006934.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100746298; called by muse, mutect2, varscan2
- SLC7A7 | c.260C>T p.A87V | Missense Mutation (SNP) | VAF 72/201 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1421138618, COSV99591714; called by muse, mutect2, varscan2
- SLC9C2 | c.2386C>T p.R796C | Missense Mutation (SNP) | VAF 43/198 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs537127323, COSV62945750; called by muse, mutect2, varscan2
- SLFN13 | c.1195C>T p.P399S | Missense Mutation (SNP) | VAF 53/123 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV99540076; called by muse, mutect2, varscan2
- SLITRK1 | c.1843G>A p.V615M | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100999985; called by muse, mutect2, varscan2
- SLITRK3 | c.1279G>A p.D427N | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs867598064, COSV53847021, COSV53851129; called by muse, mutect2, varscan2
- SLITRK4 | c.1585G>A p.E529K | Missense Mutation (SNP) | VAF 81/86 reads (94%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV100567257, COSV100567382; called by muse, mutect2, varscan2
- SMARCA4 | c.2644G>A p.E882K | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); catalogued as COSV60786460; called by muse, mutect2, varscan2
- SNAPC4 | c.3905C>T p.P1302L | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as COSV100047355; called by muse, mutect2, varscan2
- SNTG1 | c.1291C>T p.L431F | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.831); catalogued as rs1397793441, COSV52472766; called by muse, mutect2, varscan2
- SNX20 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs750713594, COSV56058092; called by muse, mutect2, varscan2
- SOGA1 | c.2368T>A p.F790I | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.49); catalogued as COSV99414214; called by muse, varscan2
- SOS1 | c.1155T>A p.S385R | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT tolerated (0.45); PolyPhen benign (0.095); catalogued as COSV101217022; called by muse, mutect2, varscan2
- SOS1 | c.1154G>A p.S385N | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT tolerated (0.41); PolyPhen benign (0.24); catalogued as COSV101217023; called by muse, mutect2, varscan2
- SPARCL1 | c.1000A>T p.N334Y | Missense Mutation (SNP) | VAF 87/177 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV99215662; called by muse, mutect2, varscan2
- SPG21 | c.473T>C p.F158S | Missense Mutation (SNP) | VAF 86/102 reads (84%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.583); catalogued as COSV99200194; called by muse, mutect2
- SPINK9 | c.216G>A p.K72= | Splice Region (SNP) | VAF 41/69 reads (59%) | catalogued as COSV64957965; called by muse, mutect2, varscan2
- SPRR3 | c.422T>C p.V141A | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.993); catalogued as COSV99768634; called by muse, mutect2, varscan2
- SPTA1 | c.3847G>A p.E1283K | Missense Mutation (SNP) | VAF 133/186 reads (72%) | SIFT deleterious (0.02); PolyPhen benign (0.34); catalogued as COSV100935116; called by muse, mutect2, varscan2
- SPTBN4 | c.5666C>T p.S1889F | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.942); catalogued as rs1450343722, COSV100151174; called by muse, mutect2, varscan2
- SSH1 | c.827T>A p.I276N | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV100425620; called by muse, mutect2, varscan2
- ST6GALNAC5 | c.971C>T p.S324L | Missense Mutation (SNP) | VAF 31/87 reads (36%) | PolyPhen benign (0.02); catalogued as COSV100602807; called by muse, mutect2, varscan2
- ST8SIA5 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 76/188 reads (40%) | PolyPhen benign (0.015); catalogued as rs772209308, COSV59330330; called by muse, mutect2, varscan2
- STAC3 | c.38C>T p.S13F | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV60416511; called by muse, mutect2, varscan2
- STAG1 | c.640C>T p.Q214* | Nonsense Mutation (SNP) | VAF 45/90 reads (50%) | catalogued as COSV99365835; called by muse, mutect2, varscan2
- STARD13 | c.613G>A p.G205S (on ENST00000336934 / NM_001243476.3; = p.G87S on NM_052851.3) | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.32); PolyPhen benign (0.145); catalogued as COSV99716017; called by muse, mutect2, varscan2
- STEAP4 | c.577C>T p.P193S | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100112605; called by muse, mutect2, varscan2
- STIP1 | c.632C>A p.P211Q | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.627); catalogued as COSV100534901; called by muse, mutect2, varscan2
- STXBP5L | c.2959G>A p.V987I | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.183); catalogued as COSV99874695; called by muse, mutect2, varscan2
- SUCLG1 | c.809T>C p.L270S | Missense Mutation (SNP) | VAF 56/144 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1380063430, CM156696, COSV101205431; called by muse, mutect2, varscan2
- SULT1C2 | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as rs112864909, COSV52264611; called by muse, mutect2, varscan2
- SYNE2 | c.7445A>T p.N2482I | Missense Mutation (SNP) | VAF 65/115 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as COSV100647900; called by muse, mutect2, varscan2
- SYNE3 | c.190G>A p.V64M | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs757884469, COSV62080090; called by muse, mutect2, varscan2
- SYNPO | c.2273C>T p.S758F (on ENST00000394243 / NM_001166208.2; = p.S514F on NM_007286.6) | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100302219; called by muse, mutect2, varscan2
- SYT10 | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.768); catalogued as COSV57345429; called by muse, mutect2, varscan2
- SYT11 | c.205C>T p.L69F | Missense Mutation (SNP) | VAF 87/122 reads (71%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100851319; called by muse, mutect2, varscan2
- TACC2 | c.1651G>A p.D551N | Missense Mutation (SNP) | VAF 46/84 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0.211); catalogued as COSV100552588; called by muse, varscan2
- TACC2 | c.1655G>A p.G552E | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100552590; called by muse, varscan2
- TBX10 | c.490C>T p.Q164* | Nonsense Mutation (SNP) | VAF 48/90 reads (53%) | catalogued as COSV100039784; called by muse, varscan2
- TBX10 | c.482G>A p.W161* | Nonsense Mutation (SNP) | VAF 34/90 reads (38%) | catalogued as rs1207744821, COSV100039786; called by muse, varscan2
- TEK | c.264G>A p.W88* | Nonsense Mutation (SNP) | VAF 31/72 reads (43%) | catalogued as COSV101193100; called by muse, mutect2, varscan2
- TESPA1 | c.1529C>T p.P510L (on ENST00000316577 / NM_001098815.3; = p.P372L on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 84/205 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV100345319; called by muse, mutect2, varscan2
- TGIF2 | c.40T>G p.S14A | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT tolerated (0.51); PolyPhen benign (0.206); catalogued as COSV100872302; called by muse, mutect2, varscan2
- TGIF2 | c.41C>T p.S14F | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.477); catalogued as COSV65836918; called by muse, mutect2, varscan2
- THEM5 | c.262T>G p.F88V | Missense Mutation (SNP) | VAF 164/242 reads (68%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV100917250; called by muse, mutect2, varscan2
- THSD7B | c.2095C>T p.Q699* | Nonsense Mutation (SNP) | VAF 17/34 reads (50%) | catalogued as COSV99747067, COSV99752629; called by muse, mutect2, varscan2
- TLL1 | c.1762C>A p.Q588K | Missense Mutation (SNP) | VAF 59/125 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99286509; called by muse, mutect2, varscan2
- TMEM131L | c.4735C>T p.R1579C | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs764856494, COSV53647287; called by muse, mutect2, varscan2
- TMEM192 | c.39T>A p.D13E | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as COSV100122121; called by muse, mutect2, varscan2
- TMTC3 | c.1088C>T p.S363L | Missense Mutation (SNP) | VAF 75/156 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754151330, COSV99898427; called by muse, mutect2, varscan2
- TNKS | c.2260C>G p.L754V | Missense Mutation (SNP) | VAF 55/125 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV100127240; called by muse, mutect2, varscan2
- TNR | c.1258G>A p.G420R | Missense Mutation (SNP) | VAF 130/181 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54886088; called by muse, mutect2, varscan2
- TNXB | c.893A>G p.N298S | Missense Mutation (SNP) | VAF 18/20 reads (90%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV100926405; called by muse, mutect2, varscan2
- TP53BP1 | c.2713C>T p.H905Y | Missense Mutation (SNP) | VAF 39/71 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs761309980, COSV99780738; called by muse, mutect2, varscan2
- TRAPPC2L | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 46/89 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs772201015, COSV51938896, COSV99243236; called by muse, mutect2, varscan2
- TRIM2 | c.1637A>G p.D546G (on ENST00000437508; = p.D573G on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/100 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV100108001; called by muse, mutect2, varscan2
- TRIM42 | c.1748C>T p.S583F | Missense Mutation (SNP) | VAF 56/111 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.037); catalogued as COSV99648450; called by muse, mutect2, varscan2
- TRIM6 | c.728G>A p.G243E | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV99546487; called by muse, mutect2
- TRMT12 | c.657T>A p.F219L | Missense Mutation (SNP) | VAF 87/180 reads (48%) | SIFT tolerated (0.35); PolyPhen benign (0.03); catalogued as COSV100149213; called by muse, mutect2, varscan2
- TRPC7 | c.784G>A p.D262N | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.379); catalogued as COSV61452907; called by muse, mutect2, varscan2
- TRPM6 | c.2513C>T p.P838L | Missense Mutation (SNP) | VAF 58/109 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62522859; called by muse, mutect2, varscan2
- TRRAP | c.10957G>C p.E3653Q (on ENST00000359863 / NM_001244580.1; = p.E3624Q on NM_003496.3) | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.101); catalogued as COSV100705434, COSV100705489; called by muse, mutect2, varscan2
- TTBK1 | c.3469C>T p.P1157S | Missense Mutation (SNP) | VAF 19/19 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1276098660, COSV99444833; called by muse, mutect2, varscan2
- TTC13 | c.2283T>A p.N761K | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100792943; called by muse, mutect2, varscan2
- TTN | c.31205C>T p.S10402F (on ENST00000591111; = p.S9475F on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/97 reads (43%) | PolyPhen possibly damaging (0.588); catalogued as COSV60340576; called by muse, mutect2, varscan2
- TTN | c.25942G>A p.E8648K (on ENST00000591111; = p.E7721K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/29 reads (45%) | PolyPhen benign (0.359); catalogued as rs200325324, COSV60460251; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.13891C>T p.P4631S (on ENST00000591111; = p.P3704S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/43 reads (21%) | PolyPhen possibly damaging (0.657); catalogued as COSV100617621; called by muse, mutect2, varscan2
- TTN | c.9395G>A p.G3132E (on ENST00000591111; = p.G3086E on NM_003319.4) | Missense Mutation (SNP) | VAF 43/115 reads (37%) | PolyPhen probably damaging (1); catalogued as rs1293502713, COSV100617625, COSV59893010; called by muse, mutect2, varscan2
- TTN | c.2351G>A p.G784E (on ENST00000591111; = p.G738E on NM_003319.4) | Missense Mutation (SNP) | VAF 36/84 reads (43%) | PolyPhen benign (0.006); catalogued as COSV100617629; called by muse, mutect2, varscan2
- TUBAL3 | c.356C>T p.S119L | Missense Mutation (SNP) | VAF 100/162 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.092); catalogued as rs782507211, COSV66814561; called by muse, mutect2, varscan2
- TULP1 | c.605C>T p.S202F | Missense Mutation (SNP) | VAF 82/93 reads (88%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as COSV100004232; called by muse, mutect2, varscan2
- TULP4 | c.4469C>T p.T1490I | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1258376331, COSV100893565; called by muse, mutect2, varscan2
- UGT2B11 | c.907G>A p.G303S | Missense Mutation (SNP) | VAF 115/282 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV71423892; called by muse, mutect2, varscan2
- ULK4 | c.1564C>T p.P522S | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV100093179; called by muse, mutect2
- UNC79 | c.7229C>T p.S2410F (on ENST00000393151 / NM_001346218.2; = p.S2233F on NM_020818.5) | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs998192270, COSV56401543; called by muse, mutect2, varscan2
- USH2A | c.4099C>T p.P1367S | Missense Mutation (SNP) | VAF 50/69 reads (72%) | SIFT tolerated (0.41); PolyPhen benign (0.17); catalogued as COSV100236797; called by muse, mutect2, varscan2
- UTRN | c.8428C>T p.L2810F | Missense Mutation (SNP) | VAF 56/107 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV62307998; called by muse, mutect2, varscan2
- VGLL3 | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT tolerated (0.78); PolyPhen benign (0.01); catalogued as COSV67353045; called by muse, mutect2, varscan2
- VIT | c.299G>A p.G100E | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1481181574, COSV101007460; called by muse, mutect2, varscan2
- WDR49 | c.668G>A p.G223E (on ENST00000308378 / NM_001366158.1; = p.G564E on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as COSV57706517, COSV57718553; called by muse, mutect2, varscan2
- XIRP2 | c.6557C>T p.S2186L (on ENST00000628543; = p.S2361L on NM_152381.6) | Missense Mutation (SNP) | VAF 54/111 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.534); catalogued as COSV54687532; called by muse, mutect2, varscan2
- XK | c.511C>T p.L171F | Missense Mutation (SNP) | VAF 19/19 reads (100%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as rs1556450298, COSV101064724; called by muse, mutect2, varscan2
- XPOT | c.1831G>A p.E611K | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV60344801; called by muse, mutect2, varscan2
- ZFPM1 | c.1021G>T p.V341L | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.242); catalogued as rs1490595905, COSV100128502; called by muse, varscan2
- ZFYVE26 | c.898C>T p.H300Y | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (1); PolyPhen possibly damaging (0.575); catalogued as COSV100720496; called by muse, mutect2, varscan2
- ZNF257 | c.1639G>A p.E547K | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.152); catalogued as COSV101448112; called by muse, mutect2, varscan2
- ZNF530 | c.37T>A p.F13I | Missense Mutation (SNP) | VAF 55/133 reads (41%) | SIFT tolerated (0.4); PolyPhen benign (0.011); catalogued as COSV100252634; called by muse, mutect2, varscan2
- ZNF536 | c.1513C>T p.R505W | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750913170, COSV62824867; called by muse, mutect2, varscan2
- ZNF597 | c.1229T>C p.L410S | Missense Mutation (SNP) | VAF 54/116 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as rs1405689930, COSV100072033; called by muse, mutect2, varscan2
- ZNF608 | c.2560T>A p.L854I | Missense Mutation (SNP) | VAF 81/147 reads (55%) | SIFT tolerated (0.28); PolyPhen benign (0.039); catalogued as COSV100101861; called by muse, mutect2, varscan2
- ZNF609 | c.494C>T p.S165F | Missense Mutation (SNP) | VAF 19/21 reads (90%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV100441205, COSV58581822; called by muse, mutect2, varscan2
- ZNF644 | c.3811C>T p.R1271* (on ENST00000337393 / NM_201269.3; = p.R49* on NM_016620.3) | Nonsense Mutation (SNP) | VAF 20/48 reads (42%) | catalogued as COSV100494387, COSV61350732; called by muse, mutect2, varscan2
- ZNF648 | c.403T>G p.L135V | Missense Mutation (SNP) | VAF 86/130 reads (66%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as COSV100374641; called by muse, mutect2, varscan2
- ZNF654 | c.2254G>A p.G752S | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.17); PolyPhen probably damaging (1); catalogued as COSV100525799; called by muse, mutect2, varscan2
- ZNF667 | c.172C>T p.R58W | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as rs748102851, COSV52634678, COSV52634845; called by muse, mutect2, varscan2
- ZNF8 | c.835C>T p.H279Y | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99544379; called by muse, mutect2, varscan2
- ZNF831 | c.4052C>T p.S1351F | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.442); catalogued as COSV100926079; called by muse, mutect2, varscan2
- ZNFX1 | c.4478G>A p.R1493H | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.039); catalogued as rs756195531, COSV100872066; called by muse, mutect2, varscan2
- ZNHIT1 | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV100522029; called by muse, mutect2, varscan2
- AKR1E2 | c.796_797delinsT p.P266Sfs*20 | Frame Shift Del (DEL) | VAF 75/217 reads (35%) | called by pindel, varscan2*
- CALCRL | c.1136del p.L379Wfs*17 | Frame Shift Del (DEL) | VAF 16/45 reads (36%) | called by mutect2, pindel, varscan2
- CASP8AP2 | c.3943_3961del p.K1315Lfs*4 | Frame Shift Del (DEL) | VAF 24/65 reads (37%) | called by mutect2, pindel, varscan2
- CFAP74 | c.548T>A p.F183Y | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.306); called by muse, varscan2
- HTT | c.6507del p.E2170Rfs*2 | Frame Shift Del (DEL) | VAF 28/72 reads (39%) | called by mutect2, pindel, varscan2
- IGKV1-5 | c.347_348del p.Y116Ffs*? | Frame Shift Del (DEL) | VAF 47/145 reads (32%) | called by mutect2, pindel, varscan2
- MLLT6 | c.842C>T p.S281F | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- OBSCN | c.10962del p.V3655Wfs*18 | Frame Shift Del (DEL) | VAF 25/148 reads (17%) | called by mutect2, pindel, varscan2
- RB1 | c.426_440del p.K143_A147del | In Frame Del (DEL) | VAF 62/218 reads (28%) | called by mutect2, pindel, varscan2
- RB1 | c.2390del p.L797Yfs*13 | Frame Shift Del (DEL) | VAF 66/158 reads (42%) | called by mutect2, pindel, varscan2
- SPATA20 | c.2130del p.Q711Rfs*22 (on ENST00000356488 / NM_001258372.1; = p.Q727Rfs*22 on NM_022827.4) | Frame Shift Del (DEL) | VAF 10/23 reads (43%) | called by mutect2, pindel*, varscan2
- TPTE | c.787C>T p.P263S (on ENST00000618007 / NM_199261.4; = p.P245S on NM_199259.4) | Missense Mutation (SNP) | VAF 47/347 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- TRBV4-2 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 100/401 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- A2M | c.3102G>A p.R1034= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as COSV100588363, COSV59389951; called by muse, mutect2, varscan2
- ABCC10 | c.1701C>T p.S567= (on ENST00000372530 / NM_001198934.2; = p.S524= on NM_033450.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 82/84 reads (98%) | catalogued as rs1408211932, COSV99767407; called by muse, mutect2, varscan2
- ACE | c.3735C>T p.F1245= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs963984458, COSV52005508; called by muse, mutect2
- ACSM1 | c.546G>A p.L182= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as COSV54639784, COSV99533086; called by muse, mutect2, varscan2
- ADAM32 | c.1110C>T p.F370= | Silent (SNP) | VAF 17/39 reads (44%) | catalogued as rs868282152, COSV101165421; called by muse, mutect2, varscan2
- ADCY8 | c.1902G>A p.G634= | Silent (SNP) | VAF 29/49 reads (59%) | catalogued as COSV53908811; called by muse, mutect2, varscan2
- ADGRB1 | c.3067C>T p.L1023= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as rs1472574360, COSV100029804; called by muse, mutect2, varscan2
- ANK1 | c.4905C>T p.I1635= | Silent (SNP) | VAF 70/197 reads (36%) | catalogued as rs1156592579, COSV55880535; called by muse, mutect2, varscan2
- ANKRD11 | c.3435G>A p.R1145= | Silent (SNP) | VAF 45/103 reads (44%) | catalogued as COSV99969705; called by muse, mutect2, varscan2
- ANKRD11 | c.168C>T p.S56= | Silent (SNP) | VAF 30/51 reads (59%) | catalogued as COSV99969708; called by muse, mutect2, varscan2
- ART1 | c.561G>A p.R187= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as rs1342167014, COSV99167188; called by muse, mutect2, varscan2
- ASXL3 | c.6528G>A p.G2176= | Silent (SNP) | VAF 61/143 reads (43%) | catalogued as COSV99325266; called by muse, mutect2, varscan2
- ATP10D | c.2967G>T p.R989= | Silent (SNP) | VAF 43/79 reads (54%) | catalogued as rs1464258313, COSV56712796; called by muse, mutect2, varscan2
- B3GALT4 | c.1131G>A p.Q377= | Silent (SNP) | VAF 82/89 reads (92%) | catalogued as COSV101005655; called by muse, mutect2, varscan2
- BAZ2B | c.5760G>A p.Q1920= | Silent (SNP) | VAF 36/77 reads (47%) | catalogued as COSV100600728; called by muse, mutect2, varscan2
- BRIP1 | c.2268C>T p.L756= | Silent (SNP) | VAF 47/80 reads (59%) | catalogued as rs864622332, COSV99370355; ClinVar: likely benign; called by muse, mutect2, varscan2
- C10orf82 | c.69C>T p.F23= | Silent (SNP) | VAF 31/61 reads (51%) | catalogued as rs781820951, COSV100980123; called by muse, mutect2, varscan2
- C3orf20 | c.1863G>A p.K621= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as COSV99514141; called by muse, mutect2, varscan2
- CACNA1B | c.1851C>T p.F617= | Silent (SNP) | VAF 15/23 reads (65%) | catalogued as rs1442216247, COSV99498015; called by muse, mutect2, varscan2
- CADPS | c.2232C>T p.I744= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as COSV51868659, COSV51903037; called by muse, mutect2, varscan2
- CARD11 | c.2073C>T p.F691= | Silent (SNP) | VAF 54/69 reads (78%) | catalogued as rs1301445086, COSV62754714; called by muse, mutect2, varscan2
- CARD11 | c.439C>T p.L147= | Silent (SNP) | VAF 82/129 reads (64%) | catalogued as rs760689603, COSV100712244; called by muse, mutect2, varscan2
- CAVIN2 | c.1077G>A p.A359= | Silent (SNP) | VAF 71/171 reads (42%) | catalogued as COSV58423144; called by muse, mutect2, varscan2
- CCDC106 | c.264C>T p.F88= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as rs1244012689, COSV99553151; called by muse, mutect2, varscan2
- CDC20B | c.58C>T p.L20= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as rs1237057563, COSV99697015; called by muse, mutect2, varscan2
- CDH4 | c.787C>T p.L263= | Silent (SNP) | VAF 34/126 reads (27%) | catalogued as COSV100849057; called by muse, mutect2, varscan2
- CDH6 | c.273C>T p.I91= | Silent (SNP) | VAF 40/93 reads (43%) | catalogued as COSV99419521; called by muse, mutect2, varscan2
- CENPE | c.1671G>A p.S557= | Silent (SNP) | VAF 22/50 reads (44%) | catalogued as rs575353274, COSV54383602; called by muse, mutect2, varscan2
- CEP85 | c.123C>T p.P41= | Silent (SNP) | VAF 16/27 reads (59%) | catalogued as COSV99432434; called by muse, mutect2, varscan2
- CFAP74 | c.550C>A p.R184= | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as rs755896597; called by muse, varscan2
- CHAF1A | c.489C>T p.A163= | Silent (SNP) | VAF 54/121 reads (45%) | catalogued as rs763499968, COSV100011271; called by muse, mutect2, varscan2
- CLIP4 | c.1731G>A p.R577= | Silent (SNP) | VAF 97/204 reads (48%) | catalogued as COSV100192009; called by muse, mutect2, varscan2
- CNTN3 | c.1959C>T p.I653= | Silent (SNP) | VAF 39/84 reads (46%) | catalogued as rs769586871, COSV99724846; called by muse, mutect2, varscan2
- COL5A2 | c.3702G>A p.G1234= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as COSV100880467; called by muse, mutect2
- COL6A6 | c.441G>A p.V147= | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as COSV100650365; called by muse, mutect2, varscan2
- CREG2 | c.606C>T p.F202= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as COSV100240535, COSV61316536; called by muse, mutect2, varscan2
- CSPG4 | c.2997C>T p.A999= | Silent (SNP) | VAF 44/93 reads (47%) | catalogued as COSV100413834; called by muse, mutect2, varscan2
- CUZD1 | c.1338C>T p.P446= | Silent (SNP) | VAF 27/44 reads (61%) | catalogued as COSV100158639, COSV100158856; called by muse, mutect2, varscan2
- CYP11A1 | c.1180C>T p.L394= | Silent (SNP) | VAF 25/52 reads (48%) | catalogued as rs1228425704, COSV99166042; called by muse, mutect2, varscan2
- CYP8B1 | c.516C>T p.F172= | Silent (SNP) | VAF 41/77 reads (53%) | catalogued as rs761431531, COSV100296189; called by muse, mutect2, varscan2
- DCAF11 | c.1614C>T p.S538= | Silent (SNP) | VAF 26/78 reads (33%) | catalogued as COSV100386730; called by muse, mutect2, varscan2
- DCC | c.3114C>T p.L1038= | Silent (SNP) | VAF 39/86 reads (45%) | catalogued as rs1169394521, COSV100500729; called by muse, mutect2, varscan2
- DCC | c.4326C>T p.I1442= | Silent (SNP) | VAF 41/97 reads (42%) | catalogued as rs141319005, COSV71436682; called by muse, mutect2, varscan2
- DCDC1 | c.1947A>G p.E649= | Silent (SNP) | VAF 3/17 reads (18%) | catalogued as COSV100663600; called by muse, mutect2
- DCLK2 | c.1284C>T p.A428= | Silent (SNP) | VAF 35/92 reads (38%) | catalogued as COSV99652292; called by muse, mutect2, varscan2
- DDX31 | c.924C>T p.A308= | Silent (SNP) | VAF 44/71 reads (62%) | catalogued as rs1225968198, COSV60136241; called by muse, mutect2, varscan2
- DENND1C | c.159C>T p.F53= | Silent (SNP) | VAF 42/94 reads (45%) | catalogued as rs1236339703, COSV101200213; called by muse, mutect2, varscan2
- DHRS13 | c.972C>T p.D324= | Silent (SNP) | VAF 16/24 reads (67%) | catalogued as COSV101128951; called by muse, mutect2, varscan2
- DHRSX | c.213C>T p.I71= | Silent (SNP) | VAF 64/141 reads (45%) | catalogued as rs901674478, COSV58134877; called by muse, mutect2, varscan2
- DNAH10 | c.6948G>A p.L2316= (on ENST00000409039; = p.L2255= on NM_207437.3) | Silent (SNP) | VAF 27/48 reads (56%) | catalogued as COSV101292333; called by muse, mutect2, varscan2
- DNAH5 | c.12348C>T p.I4116= | Silent (SNP) | VAF 29/65 reads (45%) | catalogued as COSV54252364; called by muse, mutect2, varscan2
- DNM1 | c.951C>T p.F317= | Silent (SNP) | VAF 29/49 reads (59%) | catalogued as COSV100360009; called by muse, mutect2, varscan2
- DOK5 | c.186C>T p.L62= | Silent (SNP) | VAF 50/101 reads (50%) | catalogued as COSV99374128; called by muse, mutect2, varscan2
- DRD1 | c.1173C>T p.I391= | Silent (SNP) | VAF 28/71 reads (39%) | catalogued as COSV101192474; called by muse, mutect2, varscan2
- DRD5 | c.558C>T p.A186= | Silent (SNP) | VAF 18/32 reads (56%) | catalogued as rs1336988839, COSV100431829; called by muse, mutect2, varscan2
- DSCAM | c.2103G>A p.G701= | Silent (SNP) | VAF 27/57 reads (47%) | catalogued as COSV68026501; called by muse, mutect2, varscan2
- ELAVL2 | c.600A>G p.V200= | Silent (SNP) | VAF 70/161 reads (43%) | catalogued as rs1211801035, COSV99806428; called by muse, mutect2, varscan2
- ENTHD1 | c.1035C>T p.P345= | Silent (SNP) | VAF 60/117 reads (51%) | catalogued as rs758181955, COSV100288839; called by muse, mutect2, varscan2
- ENTPD1 | c.819A>C p.A273= | Silent (SNP) | VAF 51/113 reads (45%) | catalogued as COSV100967590; called by muse, mutect2, varscan2
- EP400 | c.6099C>A p.P2033= | Silent (SNP) | VAF 96/207 reads (46%) | catalogued as COSV100201393; called by muse, mutect2, varscan2
- ERBB3 | c.3237C>T p.P1079= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs529498703, COSV99917125; called by muse, mutect2, varscan2
- ERG | c.174C>T p.V58= | Silent (SNP) | VAF 34/86 reads (40%) | catalogued as COSV55727476; called by muse, mutect2, varscan2
- ERGIC3 | c.60C>T p.F20= | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as rs1275196918, COSV99650496; called by muse, mutect2, varscan2
- ERICH3 | c.1059C>T p.F353= | Silent (SNP) | VAF 31/67 reads (46%) | catalogued as rs769875646, COSV58607407; called by muse, mutect2, varscan2
- ESYT2 | c.2196C>T p.D732= (on ENST00000613624; = p.D656= on NM_020728.3) | Silent (SNP) | VAF 26/57 reads (46%) | catalogued as COSV99276841; called by muse, mutect2, varscan2
- EVL | c.624A>G p.G208= (on ENST00000402714 / NM_001330221.2; = p.G210= on NM_016337.3) | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as COSV101233082; called by muse, varscan2
- EXOC3 | c.1989C>T p.A663= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as rs1388876742, COSV100155385; called by muse, mutect2, varscan2
- FAP | c.1836C>T p.F612= | Silent (SNP) | VAF 48/125 reads (38%) | catalogued as COSV99502239; called by muse, mutect2, varscan2
- FGF14 | c.420C>T p.T140= | Silent (SNP) | VAF 21/46 reads (46%) | catalogued as rs763749500, COSV101086562; called by muse, mutect2, varscan2
- FGF9 | c.285G>A p.L95= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV101210989; called by muse, mutect2, varscan2
- FNDC1 | c.2985G>A p.R995= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs569007075, COSV99794876; called by muse, mutect2, varscan2
- FPR1 | c.432G>A p.K144= | Silent (SNP) | VAF 38/78 reads (49%) | catalogued as COSV100494127; called by muse, mutect2, varscan2
- FSTL5 | c.1185C>T p.G395= | Silent (SNP) | VAF 95/185 reads (51%) | catalogued as rs751706523, COSV100056712; called by muse, mutect2, varscan2
- GAK | c.2554C>T p.L852= | Silent (SNP) | VAF 44/105 reads (42%) | catalogued as rs777269727, COSV100033711; called by muse, mutect2, varscan2
- GALNT16 | c.1044G>A p.R348= | Silent (SNP) | VAF 54/88 reads (61%) | catalogued as COSV100545883; called by muse, mutect2, varscan2
- GP6 | c.1009T>C p.L337= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as COSV100117583; called by muse, mutect2, varscan2
- GPATCH3 | c.477C>T p.T159= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs1363079239, COSV64652142; called by muse, mutect2, varscan2
- GPC6 | c.621G>A p.L207= | Silent (SNP) | VAF 32/66 reads (48%) | catalogued as COSV65539319; called by muse, mutect2, varscan2
- GPR119 | c.495C>T p.F165= | Silent (SNP) | VAF 30/31 reads (97%) | catalogued as rs919370770, COSV99358602, COSV99358659; called by muse, mutect2, varscan2
- GSDME | c.1050C>T p.P350= | Silent (SNP) | VAF 22/75 reads (29%) | catalogued as COSV100742359; called by muse, mutect2, varscan2
- HECTD1 | c.654C>T p.T218= | Silent (SNP) | VAF 30/58 reads (52%) | catalogued as rs774230870, COSV67948734; called by muse, mutect2, varscan2
- HIVEP3 | c.1899G>A p.K633= | Silent (SNP) | VAF 142/297 reads (48%) | catalogued as rs1259335859, COSV99912946; called by muse, mutect2, varscan2
- HTR2C | c.966C>T p.I322= | Silent (SNP) | VAF 68/74 reads (92%) | catalogued as COSV52215968; called by muse, mutect2, varscan2
- HYDIN | c.9903C>T p.I3301= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as rs575084031, COSV101151611; called by muse, mutect2, varscan2
- IFNL2 | c.453C>T p.T151= | Silent (SNP) | VAF 22/32 reads (69%) | catalogued as COSV100122094; called by muse, mutect2, varscan2
- IGHV3-73 | c.321G>A p.L107= | Silent (SNP) | VAF 72/203 reads (35%) | called by muse, mutect2, varscan2
- IL12A | c.561C>T p.I187= | Silent (SNP) | VAF 83/179 reads (46%) | catalogued as COSV99975794; called by muse, mutect2, varscan2
- IL17RC | c.381T>C p.A127= (on ENST00000295981 / NM_153461.4; = p.A56= on NM_032732.6 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 21/45 reads (47%) | catalogued as rs1358923318, COSV99925071; called by muse, mutect2, varscan2
- INHBB | c.564C>T p.V188= | Silent (SNP) | VAF 25/61 reads (41%) | catalogued as rs1558973315, COSV99735971; called by muse, mutect2, varscan2
- INPP5D | c.2541C>T p.F847= (on ENST00000445964 / NM_001017915.3; = p.F846= on NM_005541.5) | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as rs1318879556, COSV100856833; called by muse, mutect2, varscan2
- INSRR | c.3489C>T p.S1163= | Silent (SNP) | VAF 24/117 reads (21%) | catalogued as COSV100947634; called by muse, mutect2, varscan2
- ITGB8 | c.870C>T p.L290= | Silent (SNP) | VAF 40/124 reads (32%) | catalogued as rs763523589, COSV56011429; called by muse, mutect2, varscan2
- ITGBL1 | c.798G>A p.G266= | Silent (SNP) | VAF 94/242 reads (39%) | catalogued as COSV101095466; called by muse, mutect2, varscan2
- ITK | c.21G>A p.L7= | Silent (SNP) | VAF 43/88 reads (49%) | catalogued as rs367920133, COSV101439781; called by muse, mutect2, varscan2
- JAKMIP3 | c.2187G>A p.R729= | Silent (SNP) | VAF 25/55 reads (45%) | catalogued as COSV53829761; called by muse, mutect2, varscan2
- KCNB1 | c.585C>T p.S195= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as COSV100870505, COSV100870601; called by muse, mutect2, varscan2
- KCNJ8 | c.1200G>A p.R400= | Silent (SNP) | VAF 69/141 reads (49%) | catalogued as COSV53718420; called by muse, mutect2, varscan2
- KIAA1549 | c.5805C>T p.L1935= (on ENST00000422774 / NM_001164665.2; = p.L1919= on NM_020910.3) | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as rs1377299405, COSV54307620; called by muse, mutect2, varscan2
- KIAA1755 | c.2238C>T p.F746= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as rs773550200, COSV54075557; called by muse, mutect2, varscan2
- KRT35 | c.801G>A p.E267= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as rs1171240706, COSV99877807; called by muse, mutect2, varscan2
- KRT75 | c.147G>A p.R49= | Silent (SNP) | VAF 25/48 reads (52%) | catalogued as COSV99359465; called by muse, mutect2, varscan2
- LAMA2 | c.1497T>C p.R499= | Silent (SNP) | VAF 40/125 reads (32%) | catalogued as COSV101370553; called by muse, mutect2, varscan2
- LAMA3 | c.2937C>T p.S979= | Silent (SNP) | VAF 71/200 reads (36%) | catalogued as rs148470606; ClinVar: likely benign; called by muse, mutect2, varscan2
- LCE3E | c.183C>T p.H61= | Silent (SNP) | VAF 116/165 reads (70%) | catalogued as COSV100909926; called by muse, mutect2, varscan2
- LILRA2 | c.831G>A p.Q277= | Silent (SNP) | VAF 26/59 reads (44%) | catalogued as COSV52187878; called by muse, mutect2, varscan2
- LMX1A | c.423G>A p.Q141= | Silent (SNP) | VAF 44/167 reads (26%) | catalogued as rs866613599, COSV54227775; called by muse, mutect2, varscan2
- LRRC46 | c.180G>A p.R60= | Silent (SNP) | VAF 28/67 reads (42%) | catalogued as COSV99270451; called by muse, mutect2, varscan2
- LRRC52 | c.768C>T p.F256= | Silent (SNP) | VAF 87/119 reads (73%) | catalogued as rs773429734, COSV54231977; called by muse, mutect2, varscan2
- MAGEA4 | c.318C>T p.F106= | Silent (SNP) | VAF 50/56 reads (89%) | catalogued as rs866271621, COSV99367544; called by muse, mutect2, varscan2
- MAGEC1 | c.2502C>T p.F834= | Silent (SNP) | VAF 106/118 reads (90%) | catalogued as rs970535688, COSV53573935, COSV53584376; called by muse, mutect2, varscan2
- MAP3K3 | c.717C>T p.S239= | Silent (SNP) | VAF 22/52 reads (42%) | catalogued as COSV62279962; called by muse, mutect2, varscan2
- MAST3 | c.795C>T p.I265= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as rs1357705837, COSV53226475; called by muse, mutect2
- MDFI | c.504C>T p.I168= | Silent (SNP) | VAF 82/92 reads (89%) | catalogued as COSV100025675; called by muse, mutect2, varscan2
- MEIS3 | c.774G>A p.Q258= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as COSV100520479; called by muse, mutect2, varscan2
- MFSD12 | c.664C>T p.L222= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as rs770246575, COSV100281426; called by muse, mutect2, varscan2
- MGAM | c.2109C>T p.S703= | Silent (SNP) | VAF 69/190 reads (36%) | catalogued as COSV101527484; called by muse, mutect2, varscan2
- MGAT4C | c.192G>A p.L64= | Silent (SNP) | VAF 53/111 reads (48%) | catalogued as rs1171433843, COSV59831526, COSV59832412; called by muse, mutect2, varscan2
- MROH2B | c.2265C>T p.F755= | Silent (SNP) | VAF 20/40 reads (50%) | catalogued as rs868266314, COSV68189028; called by muse, mutect2, varscan2
- MUC16 | c.29019C>T p.S9673= | Silent (SNP) | VAF 22/58 reads (38%) | catalogued as rs760121716, COSV101200183; called by muse, mutect2, varscan2
- MXRA5 | c.6306C>T p.F2102= | Silent (SNP) | VAF 8/9 reads (89%) | catalogued as rs1346177537, COSV54226058; called by muse, mutect2, varscan2
- MYH13 | c.5526G>A p.K1842= | Silent (SNP) | VAF 71/131 reads (54%) | catalogued as COSV99354328; called by muse, mutect2, varscan2
- MYO15A | c.6111C>T p.P2037= | Silent (SNP) | VAF 13/22 reads (59%) | catalogued as rs1470943957, COSV99233205; called by muse, mutect2, varscan2
- MYO16 | c.3261C>T p.F1087= | Silent (SNP) | VAF 30/99 reads (30%) | catalogued as rs1157856257, COSV62752930; called by muse, mutect2, varscan2
- MYOCD | c.768C>T p.P256= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as COSV100590905; called by muse, mutect2, varscan2
- NAALADL2 | c.2040G>A p.R680= | Silent (SNP) | VAF 24/44 reads (55%) | catalogued as COSV101495325; called by muse, mutect2, varscan2
- NAV1 | c.195G>A p.K65= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV55223659, COSV99819027; called by muse, mutect2
- NEXMIF | c.3459C>T p.N1153= | Silent (SNP) | VAF 82/92 reads (89%) | catalogued as COSV50025799; called by muse, mutect2, varscan2
- NLRP11 | c.828C>T p.S276= | Silent (SNP) | VAF 30/77 reads (39%) | catalogued as rs780325706, COSV100789760; called by muse, mutect2, varscan2
- NLRP3 | c.543G>A p.R181= | Silent (SNP) | VAF 42/55 reads (76%) | catalogued as COSV60231096; called by muse, mutect2, varscan2
- NOC4L | c.1257C>T p.D419= | Silent (SNP) | VAF 21/48 reads (44%) | catalogued as rs746625024, COSV100400130; called by muse, mutect2, varscan2
- NOL11 | c.1839C>T p.I613= | Silent (SNP) | VAF 43/90 reads (48%) | catalogued as COSV99475102; called by muse, mutect2, varscan2
- NOL4 | c.1911G>A p.Q637= | Silent (SNP) | VAF 28/53 reads (53%) | catalogued as COSV99306998; called by muse, mutect2, varscan2
- NOTUM | c.627G>A p.Q209= | Silent (SNP) | VAF 5/9 reads (56%) | catalogued as COSV101293800; called by muse, mutect2, varscan2
- NPAP1 | c.1509C>T p.S503= | Silent (SNP) | VAF 104/256 reads (41%) | catalogued as COSV100275548; called by muse, mutect2, varscan2
- NTRK2 | c.235T>C p.L79= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as COSV99456015; called by muse, mutect2, varscan2
- OR10C1 | c.427C>T p.L143= (on ENST00000622521; = p.L141= on NM_013941.3) | Silent (SNP) | VAF 78/82 reads (95%) | catalogued as rs1422951751, COSV101010844; called by muse, mutect2, varscan2
- OR1N2 | c.888G>A p.R296= | Silent (SNP) | VAF 56/132 reads (42%) | catalogued as rs138808710, COSV65460651; called by muse, mutect2, varscan2
- OR2L2 | c.930G>A p.V310= | Silent (SNP) | VAF 54/238 reads (23%) | catalogued as COSV63560206; called by muse, mutect2
- OR2T11 | c.33C>A p.L11= | Silent (SNP) | VAF 24/110 reads (22%) | catalogued as rs1292345897, COSV100424853, COSV58186767; called by muse, mutect2, varscan2
- OR51V1 | c.33G>A p.T11= | Silent (SNP) | VAF 27/73 reads (37%) | catalogued as rs550954546, COSV58314225; called by muse, mutect2, varscan2
- OR52H1 | c.42C>T p.F14= (on ENST00000322653; = p.F20= on NM_001005289.1) | Silent (SNP) | VAF 25/74 reads (34%) | catalogued as COSV100497338; called by muse, mutect2, varscan2
- OR52N4 | c.426A>T p.V142= | Silent (SNP) | VAF 55/112 reads (49%) | catalogued as COSV100421695; called by muse, mutect2, varscan2
- OR52N4 | c.891G>A p.V297= | Silent (SNP) | VAF 29/82 reads (35%) | catalogued as COSV100421549; called by muse, mutect2, varscan2
- OR6C2 | c.300C>T p.F100= | Silent (SNP) | VAF 90/213 reads (42%) | catalogued as COSV100498689, COSV100498720; called by muse, mutect2, varscan2
- OR6C74 | c.708T>C p.F236= | Silent (SNP) | VAF 38/101 reads (38%) | catalogued as COSV100667750; called by muse, mutect2, varscan2
- OXGR1 | c.369C>T p.F123= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV100037029; called by muse, mutect2, varscan2
- PAGE5 | c.360T>C p.T120= | Silent (SNP) | VAF 82/95 reads (86%) | catalogued as COSV99215775; called by muse, mutect2, varscan2
- PAK6 | c.1242C>T p.G414= | Silent (SNP) | VAF 11/21 reads (52%) | catalogued as rs555138176, COSV99544620; called by muse, mutect2, varscan2
- PASD1 | c.57G>A p.R19= | Silent (SNP) | VAF 33/36 reads (92%) | catalogued as COSV64854581; called by muse, mutect2, varscan2
- PCBP3 | c.591C>T p.V197= | Silent (SNP) | VAF 27/51 reads (53%) | catalogued as rs1219120479, COSV101234322; called by muse, mutect2, varscan2
- PCDHGA1 | c.1686C>T p.I562= | Silent (SNP) | VAF 87/208 reads (42%) | catalogued as COSV100965999; called by muse, mutect2, varscan2
- PCDHGB3 | c.1296C>T p.L432= | Silent (SNP) | VAF 46/142 reads (32%) | catalogued as rs778571401, COSV99540159; called by muse, mutect2, varscan2
- PCLO | c.14937G>A p.G4979= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as rs1447915433, COSV100433666; called by muse, mutect2, varscan2
- PIK3R3 | c.261C>T p.F87= | Silent (SNP) | VAF 35/78 reads (45%) | catalogued as COSV99422301; called by muse, mutect2, varscan2
- PIP5KL1 | c.813C>T p.F271= (on ENST00000388747 / NM_001135219.2; = p.F68= on NM_173492.1) | Silent (SNP) | VAF 36/65 reads (55%) | catalogued as COSV100304868; called by muse, mutect2, varscan2
- PKHD1 | c.7212C>T p.A2404= | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as COSV100583439; called by muse, mutect2, varscan2
- PLAC8L1 | c.348C>T p.S116= | Silent (SNP) | VAF 27/69 reads (39%) | catalogued as COSV100268747; called by muse, mutect2, varscan2
- PLCH1 | c.4926G>A p.T1642= (on ENST00000340059 / NM_001130960.2; = p.T1634= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 31/54 reads (57%) | catalogued as rs773309095, COSV58191046; called by muse, mutect2, varscan2
- PLEC | c.10068C>T p.A3356= (on ENST00000322810 / NM_201380.4; = p.A3246= on NM_000445.5) | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as rs782394973, COSV100515326; called by muse, mutect2, varscan2
- PRCC | c.825C>T p.N275= | Silent (SNP) | VAF 85/110 reads (77%) | catalogued as COSV99618744; called by muse, mutect2, varscan2
- PRR23B | c.262C>T p.L88= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV100272110; called by muse, mutect2, varscan2
- PRSS36 | c.2007G>A p.R669= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as COSV99191280; called by muse, mutect2, varscan2
- PSD2 | c.1809C>T p.F603= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as COSV99217254; called by muse, mutect2, varscan2
- PTCHD3 | c.2232C>T p.I744= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as COSV71256470, COSV71256553, COSV71256834; called by muse, mutect2, varscan2
- PTPN4 | c.2346C>T p.T782= | Silent (SNP) | VAF 54/128 reads (42%) | catalogued as COSV99750439; called by muse, mutect2, varscan2
- PXDNL | c.1173G>A p.R391= | Silent (SNP) | VAF 27/72 reads (38%) | catalogued as COSV100684252; called by muse, mutect2, varscan2
- RASGEF1A | c.417C>T p.A139= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as rs765181540, COSV100988680; called by muse, mutect2, varscan2
- RASGRF2 | c.2313G>A p.Q771= | Silent (SNP) | VAF 34/91 reads (37%) | catalogued as COSV99429513; called by muse, mutect2, varscan2
- RELN | c.4773G>A p.L1591= | Silent (SNP) | VAF 53/111 reads (48%) | catalogued as COSV100633994; called by muse, mutect2, varscan2
- RGL1 | c.1818C>T p.S606= (on ENST00000360851 / NM_001297672.2; = p.S641= on NM_015149.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 47/229 reads (21%) | catalogued as rs781287059, COSV100487009; called by muse, mutect2, varscan2
- RNF112 | c.42G>A p.R14= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as COSV71978768; called by muse, varscan2
- ROCK2 | c.4092A>G p.R1364= | Silent (SNP) | VAF 112/217 reads (52%) | catalogued as COSV100255266; called by muse, mutect2, varscan2
- RPAP1 | c.2142T>C p.P714= | Silent (SNP) | VAF 26/54 reads (48%) | catalogued as rs1396761758, COSV100427179; called by muse, mutect2, varscan2
- SCNN1G | c.612C>T p.F204= | Silent (SNP) | VAF 57/129 reads (44%) | catalogued as COSV100264269, COSV55601062; called by muse, mutect2, varscan2
- SCUBE1 | c.1863A>T p.A621= | Silent (SNP) | VAF 28/83 reads (34%) | catalogued as rs1339638139, COSV100683368; called by muse, mutect2, varscan2
- SEC24C | c.3087C>T p.S1029= | Silent (SNP) | VAF 33/73 reads (45%) | catalogued as COSV100226921; called by muse, mutect2, varscan2
- SI | c.2640C>T p.I880= | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as COSV52281467, COSV52302480; called by muse, mutect2, varscan2
- SLC12A3 | c.180G>A p.T60= | Silent (SNP) | VAF 49/120 reads (41%) | catalogued as rs756508866, COSV52640061; called by muse, mutect2, varscan2
- SLC16A12 | c.1038G>A p.K346= | Silent (SNP) | VAF 27/66 reads (41%) | catalogued as rs529351922, COSV100370281; called by muse, mutect2, varscan2
- SLC26A6 | c.2085C>T p.D695= | Silent (SNP) | VAF 76/161 reads (47%) | catalogued as rs774856729, COSV100258459; called by muse, mutect2, varscan2
- SLC35F4 | c.294C>T p.S98= (on ENST00000339762 / NM_001352015.2; = p.S62= on NM_001206920.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/61 reads (34%) | catalogued as COSV60262872, COSV60265464; called by muse, mutect2, varscan2
- SLC38A4 | c.1047C>T p.V349= | Silent (SNP) | VAF 26/57 reads (46%) | catalogued as rs1405651299, COSV99872823; called by muse, mutect2, varscan2
- SLC4A8 | c.627G>A p.R209= | Silent (SNP) | VAF 35/67 reads (52%) | catalogued as COSV100177049; called by muse, mutect2, varscan2
- SLC9A4 | c.1992G>A p.G664= | Silent (SNP) | VAF 44/85 reads (52%) | catalogued as COSV54834071; called by muse, mutect2, varscan2
- SMG1 | c.6813C>T p.S2271= | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as rs1258778685, COSV101246198; called by muse, mutect2, varscan2
- SPG21 | c.471A>T p.A157= | Silent (SNP) | VAF 85/101 reads (84%) | catalogued as COSV99200195; called by muse, mutect2
- SPHK2 | c.1377G>A p.G459= | Silent (SNP) | VAF 43/102 reads (42%) | catalogued as COSV99709437; called by muse, mutect2, varscan2
- STXBP5L | c.2958G>A p.V986= | Silent (SNP) | VAF 36/82 reads (44%) | catalogued as COSV99874693; called by muse, mutect2, varscan2
- SYNRG | c.3588G>A p.E1196= | Silent (SNP) | VAF 17/39 reads (44%) | called by muse, mutect2
- SYT17 | c.1248G>A p.K416= | Silent (SNP) | VAF 17/35 reads (49%) | catalogued as rs760150714, COSV62546419; called by muse, mutect2, varscan2
- TBC1D4 | c.687C>T p.F229= | Silent (SNP) | VAF 42/133 reads (32%) | catalogued as COSV100884644; called by muse, mutect2, varscan2
- TCAF1 | c.2238C>T p.L746= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as COSV100584647; called by mutect2, varscan2
- TCF4 | c.1872G>A p.R624= | Silent (SNP) | VAF 45/135 reads (33%) | catalogued as COSV61901471; called by muse, mutect2, varscan2
- TEKT2 | c.795C>T p.F265= | Silent (SNP) | VAF 31/58 reads (53%) | catalogued as rs1368802085, COSV99255543; called by muse, mutect2, varscan2
- TENM1 | c.1092G>A p.G364= | Silent (SNP) | VAF 83/89 reads (93%) | catalogued as COSV100950282; called by muse, mutect2, varscan2
- TEX11 | c.519G>A p.K173= (on ENST00000344304; = p.K158= on NM_031276.3) | Silent (SNP) | VAF 11/14 reads (79%) | catalogued as COSV100721860, COSV60236614; called by muse, mutect2, varscan2
- TGM5 | c.1437A>G p.Q479= (on ENST00000220420 / NM_201631.4; = p.Q397= on NM_004245.4) | Silent (SNP) | VAF 21/52 reads (40%) | catalogued as rs1566827693, COSV55011359; called by muse, mutect2, varscan2
- TMEM59L | c.765C>T p.F255= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as rs1434046920, COSV53242770; called by muse, mutect2, varscan2
- TMPRSS15 | c.1302C>T p.V434= | Silent (SNP) | VAF 113/250 reads (45%) | catalogued as COSV53048175; called by muse, mutect2, varscan2
- TNC | c.501C>T p.F167= | Silent (SNP) | VAF 51/81 reads (63%) | catalogued as COSV100405910; called by muse, mutect2, varscan2
- TREM1 | c.594C>T p.I198= | Silent (SNP) | VAF 42/45 reads (93%) | catalogued as COSV55149443, COSV99776387; called by muse, mutect2, varscan2
- TRPM3 | c.4170C>T p.T1390= (on ENST00000357533 / NM_001366142.2; = p.T1245= on NM_020952.6) | Silent (SNP) | VAF 45/105 reads (43%) | catalogued as COSV100677606; called by muse, mutect2, varscan2
- TSHZ2 | c.1551G>A p.L517= | Silent (SNP) | VAF 42/87 reads (48%) | catalogued as COSV100296241, COSV61589923; called by muse, mutect2, varscan2
- TSPAN17 | c.351C>T p.F117= | Silent (SNP) | VAF 69/148 reads (47%) | catalogued as COSV100024737; called by muse, mutect2, varscan2
- TUBA3C | c.702C>T p.I234= | Silent (SNP) | VAF 68/162 reads (42%) | catalogued as rs142245280; called by muse, mutect2, varscan2
- UGT2B4 | c.1534C>T p.L512= | Silent (SNP) | VAF 73/149 reads (49%) | catalogued as COSV59320749; called by muse, mutect2, varscan2
- ULK1 | c.1263C>T p.F421= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as rs1450628567, COSV100416964; called by muse, mutect2, varscan2
- USP6NL | c.2103C>T p.L701= | Silent (SNP) | VAF 32/56 reads (57%) | catalogued as rs1406013456, COSV99509741; called by muse, mutect2, varscan2
- VWA3B | c.2217C>T p.V739= | Silent (SNP) | VAF 48/83 reads (58%) | catalogued as rs765160787, COSV68242093; called by muse, mutect2, varscan2
- WDR81 | c.5106C>T p.F1702= (on ENST00000409644 / NM_001163809.2; = p.F651= on NM_152348.4) | Silent (SNP) | VAF 21/57 reads (37%) | catalogued as rs372716005; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZCCHC13 | c.423C>T p.I141= | Silent (SNP) | VAF 19/22 reads (86%) | catalogued as rs370148394, COSV100272533; called by muse, mutect2, varscan2
- ZNF155 | c.912G>A p.K304= | Silent (SNP) | VAF 59/132 reads (45%) | catalogued as COSV99525725; called by muse, mutect2, varscan2
- ZNF160 | c.2178C>T p.I726= | Silent (SNP) | VAF 74/181 reads (41%) | catalogued as COSV100762357; called by muse, mutect2, varscan2
- ZNF18 | c.396C>T p.I132= | Silent (SNP) | VAF 81/190 reads (43%) | catalogued as rs566274334, COSV100503124; called by muse, mutect2, varscan2
- ZNF286A | c.891C>T p.L297= | Silent (SNP) | VAF 37/94 reads (39%) | catalogued as COSV101224808; called by muse, mutect2, varscan2
- ZNF653 | c.1212G>A p.E404= | Silent (SNP) | VAF 22/76 reads (29%) | catalogued as COSV99542176; called by muse, mutect2, varscan2
- ZNF93 | c.1284A>G p.E428= | Silent (SNP) | VAF 53/125 reads (42%) | catalogued as COSV100652314; called by muse, mutect2, varscan2
- ZNHIT1 | c.129C>T p.D43= | Silent (SNP) | VAF 42/90 reads (47%) | catalogued as COSV100522028; called by muse, mutect2, varscan2
- ARPP19P2 | n.150G>A | RNA (SNP) | VAF 28/67 reads (42%) | catalogued as rs1335569032; called by muse, mutect2, varscan2
- EFNA4 | c.*30G>A | 3'UTR (SNP) | VAF 39/180 reads (22%) | catalogued as COSV100699661; called by muse, mutect2, varscan2
- HAO2 | c.-8-383G>A | Intron (SNP) | VAF 16/40 reads (40%) | catalogued as COSV100378076; called by muse, mutect2, varscan2
- KCNU1 | c.2010-17075C>T | Intron (SNP) | VAF 24/42 reads (57%) | called by muse, mutect2, varscan2
- LRRC27 | c.1073+1138C>T | Intron (SNP) | VAF 8/22 reads (36%) | catalogued as COSV100689832; called by muse, mutect2, varscan2
- MOBP | c.*44G>A | 3'UTR (SNP) | VAF 20/54 reads (37%) | catalogued as rs1315778482, COSV100215565; called by muse, mutect2, varscan2
- PKD2L2 | c.*18-2262C>T | Intron (SNP) | VAF 56/122 reads (46%) | catalogued as COSV99221476; called by muse, mutect2, varscan2
- RPIA | c.-1G>A | 5'UTR (SNP) | VAF 12/31 reads (39%) | catalogued as rs1340473392, COSV99376223; called by muse, mutect2, varscan2
- RRM2 | n.702C>T | RNA (SNP) | VAF 40/93 reads (43%) | called by muse, mutect2, varscan2
- SNORD115-4 | n.66G>A | RNA (SNP) | VAF 146/331 reads (44%) | called by muse, mutect2, varscan2
- SNORD116-2 | chr15:25056955 A>G | 3'Flank (SNP) | VAF 70/174 reads (40%) | called by muse, mutect2, varscan2
- THRA | c.1110+46C>T | Intron (SNP) | VAF 49/109 reads (45%) | catalogued as COSV99225565; called by muse, mutect2, varscan2
- UBTFL2 | n.792C>T | RNA (SNP) | VAF 26/64 reads (41%) | catalogued as rs377504869; called by muse, mutect2, varscan2
